Somatic mutation profile of tumor specimen HCM-BROD-0954-C34-01A (aliquot HCM-BROD-0954-C34-01A-11D-A87L-36) from HCMI case HCM-BROD-0954-C34, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Lung, NOS; AJCC pathologic stage: Stage IB; Tumor grade: G3; Age at diagnosis: 66.3 years (24,222 days).
Specimen HCM-BROD-0954-C34-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e8f6be55-d83a-4ad4-839d-408d9588c5b0.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HCM-BROD-0954-C34-10A (Blood Derived Normal), aliquot HCM-BROD-0954-C34-10A-01D-A87L-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/c8d536b6-ad7d-4881-ab6f-439ef3c9256f

The open-access MAF lists 806 somatic variants for this specimen: 567 protein-altering or splice-affecting, 200 silent, 39 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 502, Silent 200, Nonsense Mutation 41, Intron 23, Frame Shift Del 15, Frame Shift Ins 5, RNA 4, 5'Flank 4, 5'UTR 4, 3'UTR 4, Splice Site 2, Splice Region 1.

Variants (750 of 806; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CDKN1B | c.285dup p.K96Qfs*29 | Frame Shift Ins (INS) | VAF 60/691 reads (9%) | catalogued as rs1555085575, COSV99963918; ClinVar: pathogenic; called by mutect2, pindel
- TP53 | c.423C>G p.C141W | Missense Mutation (SNP) | VAF 168/521 reads (32%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1057519977, COSV52671863, COSV52706449, COSV52741627, COSV52827803; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ADAMTS20 | c.2267G>T p.G756V | Missense Mutation (SNP) | VAF 52/394 reads (13%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as rs1211908861; called by muse, mutect2, varscan2
- ADCY8 | c.3280G>T p.G1094C | Missense Mutation (SNP) | VAF 67/376 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53895143, COSV53925697; called by muse, mutect2, varscan2
- AHNAK2 | c.7101C>G p.S2367R | Missense Mutation (SNP) | VAF 58/386 reads (15%) | SIFT tolerated (0.2); PolyPhen benign (0.238); catalogued as COSV100318347; called by muse, mutect2
- AK7 | c.58G>T p.V20L | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT tolerated (0.1); PolyPhen benign (0.055); catalogued as rs1281292214; called by muse, mutect2, varscan2
- ANK2 | c.2899G>T p.G967C | Missense Mutation (SNP) | VAF 40/216 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV52176977; called by muse, mutect2, varscan2
- ANO3 | c.812C>A p.P271Q | Missense Mutation (SNP) | VAF 91/465 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV99881410; called by muse, mutect2, varscan2
- ANO4 | c.2584C>A p.R862S (on ENST00000392977 / NM_001286615.2; = p.R827S on NM_178826.4) | Missense Mutation (SNP) | VAF 83/421 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54595545; called by muse, mutect2, varscan2
- APOA4 | c.480C>G p.Y160* | Nonsense Mutation (SNP) | VAF 72/703 reads (10%) | catalogued as COSV100759252, COSV63360358; called by muse, mutect2, varscan2
- APOB | c.2410C>A p.R804S | Missense Mutation (SNP) | VAF 90/473 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.316); catalogued as COSV99264638; called by muse, mutect2, varscan2
- ARHGEF12 | c.4013G>C p.R1338P | Missense Mutation (SNP) | VAF 108/420 reads (26%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0); catalogued as COSV63105097, COSV63107934; called by muse, mutect2, varscan2
- ASL | c.301G>C p.G101R | Missense Mutation (SNP) | VAF 43/421 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59189417; called by muse, mutect2, varscan2
- B3GNT8 | c.700C>T p.R234C | Missense Mutation (SNP) | VAF 54/520 reads (10%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.448); catalogued as rs758478385, COSV99524451; called by muse, mutect2, varscan2
- BPI | c.422G>T p.G141V (on ENST00000262865; = p.G137V on NM_001725.3) | Missense Mutation (SNP) | VAF 50/357 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as rs193123151; called by muse, mutect2, varscan2
- BPIFB1 | c.455G>A p.R152H | Missense Mutation (SNP) | VAF 73/554 reads (13%) | SIFT tolerated (0.54); PolyPhen benign (0.011); catalogued as rs776047607, COSV53606515; called by muse, mutect2, varscan2
- BTNL2 | c.1294G>C p.D432H | Missense Mutation (SNP) | VAF 123/551 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.653); catalogued as COSV66630896; called by muse, mutect2, varscan2
- C1QTNF6 | c.236G>T p.R79L | Missense Mutation (SNP) | VAF 46/414 reads (11%) | SIFT tolerated (0.37); PolyPhen benign (0); catalogued as COSV55396338; called by muse, mutect2, varscan2
- CACNA2D1 | c.1921C>T p.Q641* (on ENST00000356253 / NM_001366867.1; = p.Q622* on NM_000722.4) | Nonsense Mutation (SNP) | VAF 43/235 reads (18%) | catalogued as rs1554338711; called by muse, mutect2, varscan2
- CALN1 | c.643C>G p.R215G (on ENST00000329008 / NM_001017440.3; = p.R257G on NM_031468.4) | Missense Mutation (SNP) | VAF 50/299 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.997); catalogued as COSV61119545; called by muse, mutect2, varscan2
- CARS2 | c.247T>C p.Y83H | Missense Mutation (SNP) | VAF 42/440 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1566364834; called by muse, mutect2
- CASQ1 | c.693C>G p.F231L | Missense Mutation (SNP) | VAF 85/295 reads (29%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.495); catalogued as COSV63624473; called by muse, mutect2, varscan2
- CCDC74A | c.1030C>A p.R344S | Missense Mutation (SNP) | VAF 74/464 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.475); catalogued as COSV54605064; called by muse, mutect2, varscan2
- CD33 | c.270C>A p.F90L | Missense Mutation (SNP) | VAF 53/563 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.978); catalogued as COSV51805365; called by muse, mutect2
- CFAP47 | c.8345-1G>T p.X2782_splice | Splice Site (SNP) | VAF 40/192 reads (21%) | catalogued as rs1556011615; called by mutect2, varscan2
- CHML | c.1199A>G p.Y400C | Missense Mutation (SNP) | VAF 67/562 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs547660354; called by muse, mutect2, varscan2
- CHRNA6 | c.449C>T p.P150L | Missense Mutation (SNP) | VAF 82/522 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1486057766; called by muse, mutect2, varscan2
- CHST8 | c.1093C>A p.P365T | Missense Mutation (SNP) | VAF 74/854 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV99381259; called by muse, mutect2
- CLCN4 | c.1321G>A p.A441T | Missense Mutation (SNP) | VAF 102/606 reads (17%) | SIFT tolerated (0.1); PolyPhen benign (0.088); catalogued as rs1280248831; called by muse, mutect2, varscan2
- CNTNAP5 | c.674G>A p.R225H | Missense Mutation (SNP) | VAF 92/461 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.136); catalogued as rs760438818, COSV70470252; called by muse, mutect2, varscan2
- COL14A1 | c.1325C>A p.A442D | Missense Mutation (SNP) | VAF 51/313 reads (16%) | SIFT tolerated (0.11); PolyPhen benign (0.255); catalogued as rs1453839560; called by muse, mutect2, varscan2
- CXADR | c.5C>T p.A2V | Missense Mutation (SNP) | VAF 57/412 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0); catalogued as rs1431285610; called by muse, mutect2, varscan2
- CYLC1 | c.1774G>T p.G592W | Missense Mutation (SNP) | VAF 82/460 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV61416019; called by muse, mutect2, varscan2
- DHDH | c.340C>T p.R114* | Nonsense Mutation (SNP) | VAF 100/435 reads (23%) | catalogued as rs757425465, COSV99668451; called by muse, mutect2, varscan2
- DLX5 | c.158del p.G53Efs*28 | Frame Shift Del (DEL) | VAF 61/489 reads (12%) | catalogued as COSV56034256; called by mutect2, pindel, varscan2
- DNAH10 | c.12919G>T p.V4307L (on ENST00000409039; = p.V4246L on NM_207437.3) | Missense Mutation (SNP) | VAF 98/628 reads (16%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as COSV99435262; called by muse, mutect2, varscan2
- DPPA2 | c.601G>C p.A201P | Missense Mutation (SNP) | VAF 82/379 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.583); catalogued as COSV101524730; called by muse, mutect2, varscan2
- DSC2 | c.2635G>A p.D879N | Missense Mutation (SNP) | VAF 79/410 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.513); catalogued as COSV51864031; called by muse, mutect2, varscan2
- DSE | c.2752A>G p.M918V | Missense Mutation (SNP) | VAF 46/389 reads (12%) | SIFT tolerated, low confidence (0.93); PolyPhen benign (0); catalogued as rs780791978, COSV59064011; called by muse, mutect2, varscan2
- DSEL | c.1043A>C p.Y348S | Missense Mutation (SNP) | VAF 64/700 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59494128; called by muse, mutect2
- DUSP1 | c.319G>T p.G107C | Missense Mutation (SNP) | VAF 129/355 reads (36%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.749); catalogued as rs1020876628; called by muse, mutect2, varscan2
- EFHD2 | c.479C>T p.A160V | Missense Mutation (SNP) | VAF 128/545 reads (23%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.484); catalogued as rs1296899812; called by muse, mutect2, varscan2
- EIF2AK4 | c.4273A>G p.T1425A | Missense Mutation (SNP) | VAF 36/378 reads (10%) | SIFT tolerated (0.51); PolyPhen benign (0.001); catalogued as rs1221664821; called by muse, mutect2
- EPHA5 | c.1636G>T p.A546S | Missense Mutation (SNP) | VAF 78/375 reads (21%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.913); catalogued as COSV56678728; called by muse, mutect2, varscan2
- ERVV-1 | c.878C>A p.T293K | Missense Mutation (SNP) | VAF 147/558 reads (26%) | SIFT tolerated (0.98); PolyPhen benign (0.137); catalogued as rs745614848; called by muse, mutect2, varscan2
- ESPL1 | c.4053C>A p.D1351E | Missense Mutation (SNP) | VAF 66/569 reads (12%) | SIFT tolerated (0.23); PolyPhen benign (0); catalogued as COSV57762754; called by muse, mutect2, varscan2
- ETV1 | c.1159G>A p.D387N | Missense Mutation (SNP) | VAF 48/593 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV54148151; called by muse, mutect2
- EXOC1 | c.1670G>T p.G557V | Missense Mutation (SNP) | VAF 31/328 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.076); catalogued as COSV62121420; called by muse, mutect2, varscan2
- EXT1 | c.1237G>T p.E413* | Nonsense Mutation (SNP) | VAF 70/499 reads (14%) | catalogued as CD053568; called by muse, mutect2, varscan2
- FAM47B | c.1520G>T p.R507M | Missense Mutation (SNP) | VAF 134/805 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.346); catalogued as COSV61454222; called by muse, mutect2, varscan2
- FAT3 | c.1279G>T p.G427C | Missense Mutation (SNP) | VAF 73/341 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs758156812, COSV53130348; called by muse, mutect2, varscan2
- FGF21 | c.435C>A p.H145Q | Missense Mutation (SNP) | VAF 75/739 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.062); catalogued as rs1371086194; called by muse, mutect2
- FGL1 | c.54G>T p.R18S | Missense Mutation (SNP) | VAF 42/424 reads (10%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as COSV67713231; called by muse, mutect2
- FHOD3 | c.2531C>A p.P844H (on ENST00000359247 / NM_001281739.3; = p.P861H on NM_025135.5) | Missense Mutation (SNP) | VAF 78/347 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV57187524; called by muse, mutect2, varscan2
- FLI1 | c.286G>T p.E96* | Nonsense Mutation (SNP) | VAF 104/532 reads (20%) | catalogued as COSV99857948; called by muse, mutect2, varscan2
- FMNL3 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 98/446 reads (22%) | SIFT tolerated (0.18); PolyPhen benign (0.003); catalogued as rs769025035, COSV53299199; called by muse, mutect2, varscan2
- FNDC7 | c.995C>T p.T332I | Missense Mutation (SNP) | VAF 66/587 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1408368566; called by muse, mutect2, varscan2
- FREM2 | c.4986G>T p.K1662N | Missense Mutation (SNP) | VAF 30/306 reads (10%) | SIFT tolerated (0.07); PolyPhen benign (0.177); catalogued as COSV99746760; called by muse, mutect2, varscan2
- FSCB | c.874C>T p.Q292* | Nonsense Mutation (SNP) | VAF 87/521 reads (17%) | catalogued as COSV61218660; called by muse, mutect2, varscan2
- FYN | c.44C>T p.T15M | Missense Mutation (SNP) | VAF 49/441 reads (11%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.097); catalogued as rs140762956, COSV57614854; called by muse, mutect2, varscan2
- GANAB | c.589G>T p.D197Y | Missense Mutation (SNP) | VAF 62/649 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.018); catalogued as rs772866333; called by muse, mutect2
- GAPVD1 | c.2343G>T p.K781N | Missense Mutation (SNP) | VAF 32/227 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.966); catalogued as COSV99783218; called by mutect2, varscan2
- GBP4 | c.503G>T p.R168M | Missense Mutation (SNP) | VAF 37/324 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as COSV63252871; called by muse, mutect2, varscan2
- GK2 | c.848G>T p.C283F | Missense Mutation (SNP) | VAF 107/386 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1171405467, COSV62627274; called by muse, mutect2, varscan2
- GNAS | c.466C>A p.P156T | Missense Mutation (SNP) | VAF 43/466 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.554); catalogued as COSV58347186; called by muse, mutect2
- GRM4 | c.587C>A p.S196Y | Missense Mutation (SNP) | VAF 53/533 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV65216087; called by muse, mutect2, varscan2
- GTF3C1 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 76/404 reads (19%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); catalogued as rs755821649; called by muse, mutect2, varscan2
- GUCY1A2 | c.1681G>C p.D561H | Missense Mutation (SNP) | VAF 22/286 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56496871; called by muse, mutect2
- H3C12 | c.4G>T p.A2S | Missense Mutation (SNP) | VAF 53/280 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.164); catalogued as rs897588547; called by muse, mutect2, varscan2
- HCN4 | c.1169G>T p.R390L | Missense Mutation (SNP) | VAF 34/293 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56084696; called by muse, mutect2, varscan2
- HOXA7 | c.467C>T p.T156M | Missense Mutation (SNP) | VAF 171/737 reads (23%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.998); catalogued as rs559344881, COSV54217061; called by muse, mutect2, varscan2
- IFT52 | c.472G>T p.G158* | Nonsense Mutation (SNP) | VAF 32/260 reads (12%) | catalogued as COSV100887560; called by muse, mutect2, varscan2
- IL18RAP | c.537C>G p.S179R | Missense Mutation (SNP) | VAF 77/405 reads (19%) | SIFT tolerated (0.13); PolyPhen benign (0.412); catalogued as rs1280903506; called by muse, mutect2, varscan2
- ITGA5 | c.480C>A p.Y160* | Nonsense Mutation (SNP) | VAF 51/352 reads (14%) | catalogued as COSV53218987; called by muse, mutect2, varscan2
- ITGAD | c.231C>G p.I77M | Missense Mutation (SNP) | VAF 47/416 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV66757758; called by muse, mutect2, varscan2
- JADE3 | c.1561G>T p.G521W | Missense Mutation (SNP) | VAF 47/292 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54470100; called by muse, mutect2, varscan2
- JCAD | c.2054G>C p.R685P | Missense Mutation (SNP) | VAF 102/500 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.219); catalogued as COSV64760163; called by muse, mutect2, varscan2
- KCNH6 | c.2626C>A p.P876T | Missense Mutation (SNP) | VAF 107/532 reads (20%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0.079); catalogued as COSV59007020; called by muse, mutect2, varscan2
- KDM5B | c.3848G>A p.G1283D | Missense Mutation (SNP) | VAF 37/440 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.005); catalogued as rs1464747770; called by muse, mutect2
- KEAP1 | c.1802G>C p.R601P | Missense Mutation (SNP) | VAF 123/470 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV50266847; called by muse, mutect2, varscan2
- KIF17 | c.1321A>G p.M441V | Missense Mutation (SNP) | VAF 62/510 reads (12%) | SIFT deleterious (0.03); PolyPhen benign (0.085); catalogued as rs1317971715; called by muse, mutect2, varscan2
- KIR3DL3 | c.1036T>C p.W346R | Missense Mutation (SNP) | VAF 32/468 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.972); catalogued as rs752114211, COSV52547447; called by muse, mutect2
- KRT75 | c.1426A>T p.T476S | Missense Mutation (SNP) | VAF 59/372 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.006); catalogued as COSV52874820; called by muse, mutect2
- LAMA4 | c.919G>C p.A307P (on ENST00000230538 / NM_001105206.3; = p.A300P on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 51/480 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.964); catalogued as COSV57893745, COSV57906568; called by muse, mutect2, varscan2
- LIME1 | c.98G>T p.R33M | Missense Mutation (SNP) | VAF 43/329 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs1372812557; called by muse, mutect2, varscan2
- LIN28B | c.376G>A p.G126R | Missense Mutation (SNP) | VAF 42/204 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.646); catalogued as COSV61496593, COSV61497498; called by muse, mutect2, varscan2
- LONRF1 | c.1127C>T p.P376L | Missense Mutation (SNP) | VAF 61/360 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.001); catalogued as rs760751768; called by muse, mutect2, varscan2
- LPCAT2 | c.530G>T p.R177I | Missense Mutation (SNP) | VAF 69/365 reads (19%) | SIFT deleterious (0.04); PolyPhen benign (0.305); catalogued as rs775039999; called by muse, mutect2, varscan2
- LRP1 | c.5843G>T p.R1948L | Missense Mutation (SNP) | VAF 117/580 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV99674143; called by muse, mutect2, varscan2
- LRP1B | c.10378C>A p.P3460T | Missense Mutation (SNP) | VAF 79/505 reads (16%) | SIFT tolerated (0.08); PolyPhen benign (0.272); catalogued as COSV101257804; called by muse, mutect2, varscan2
- LRPPRC | c.56G>C p.R19P | Missense Mutation (SNP) | VAF 57/511 reads (11%) | SIFT tolerated (0.15); PolyPhen benign (0.32); catalogued as rs1242185696; called by muse, mutect2, varscan2
- LRRC40 | c.1329G>T p.R443S | Missense Mutation (SNP) | VAF 34/232 reads (15%) | SIFT tolerated (0.13); PolyPhen possibly damaging (0.702); catalogued as rs1346885549, COSV100918861, COSV100918878; called by muse, mutect2, varscan2
- LUC7L | c.614G>T p.R205L | Missense Mutation (SNP) | VAF 86/446 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs1232659702; called by muse, mutect2, varscan2
- MAGEB10 | c.427C>G p.Q143E | Missense Mutation (SNP) | VAF 129/674 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.068); catalogued as rs759188030; called by muse, mutect2, varscan2
- MAGI3 | c.760G>T p.A254S | Missense Mutation (SNP) | VAF 27/237 reads (11%) | SIFT tolerated (0.21); PolyPhen benign (0.009); catalogued as rs374232138, COSV56829029; called by muse, mutect2, varscan2
- MAPK8 | c.498G>T p.K166N | Missense Mutation (SNP) | VAF 83/298 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100827582; called by muse, mutect2, varscan2
- MFAP5 | c.298C>T p.P100S | Missense Mutation (SNP) | VAF 38/438 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1433247449; called by muse, mutect2
- MMUT | c.250G>A p.E84K | Missense Mutation (SNP) | VAF 58/481 reads (12%) | SIFT tolerated, low confidence (0.31); PolyPhen benign (0.275); catalogued as CM941071, COSV104389442, COSV99222365; called by muse, mutect2, varscan2
- MPEG1 | c.1220C>A p.T407N | Missense Mutation (SNP) | VAF 85/419 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV57091163; called by muse, mutect2, varscan2
- MSC | c.10G>T p.G4C | Missense Mutation (SNP) | VAF 49/341 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.924); catalogued as COSV57696286; called by muse, mutect2, varscan2
- MTCL1 | c.2320G>A p.G774R (on ENST00000306329 / NM_001378206.1; = p.G414R on NM_015210.4) | Missense Mutation (SNP) | VAF 122/605 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV60410936; called by muse, mutect2, varscan2
- MTIF3 | c.274G>A p.E92K | Missense Mutation (SNP) | VAF 40/456 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.739); catalogued as rs1468376785; called by muse, mutect2
- MYLK2 | c.169C>T p.P57S | Missense Mutation (SNP) | VAF 68/554 reads (12%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0); catalogued as rs377211647; called by muse, mutect2, varscan2
- MYO16 | c.521C>A p.S174Y | Missense Mutation (SNP) | VAF 35/371 reads (9%) | SIFT tolerated (0.78); PolyPhen benign (0.007); catalogued as COSV99194984; called by muse, mutect2, varscan2
- NCOA3 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 86/472 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.093); catalogued as rs1200320359, COSV59069121; called by muse, mutect2, varscan2
- NELL1 | c.1577G>A p.G526D | Missense Mutation (SNP) | VAF 50/291 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV54301006; called by muse, mutect2, varscan2
- NEURL1 | c.860C>A p.P287Q | Missense Mutation (SNP) | VAF 82/322 reads (25%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as rs1191556438; called by muse, mutect2, varscan2
- NLRP12 | c.2409G>A p.M803I | Missense Mutation (SNP) | VAF 76/298 reads (26%) | SIFT tolerated (0.14); PolyPhen benign (0.049); catalogued as rs1382727542; called by muse, mutect2
- NPAP1 | c.1150G>T p.D384Y | Missense Mutation (SNP) | VAF 65/361 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.94); catalogued as COSV61508831; called by muse, mutect2, varscan2
- NPAP1 | c.3286C>T p.Q1096* | Nonsense Mutation (SNP) | VAF 51/513 reads (10%) | catalogued as rs1406443783; called by muse, mutect2
- NPAS3 | c.234G>C p.L78F (on ENST00000356141 / NM_001164749.2; = p.L48F on NM_022123.3) | Missense Mutation (SNP) | VAF 99/498 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58097916; called by muse, mutect2, varscan2
- NRG1 | c.751A>G p.I251V (on ENST00000405005 / NM_013964.5; = p.I256V on NM_013956.5) | Missense Mutation (SNP) | VAF 68/450 reads (15%) | SIFT tolerated (0.98); PolyPhen possibly damaging (0.506); catalogued as rs778488862, COSV55157851; called by muse, mutect2, varscan2
- NT5DC4 | c.11G>A p.W4* | Nonsense Mutation (SNP) | VAF 118/603 reads (20%) | catalogued as rs1452441364; called by muse, mutect2, varscan2
- OR10S1 | c.82G>T p.E28* | Nonsense Mutation (SNP) | VAF 98/471 reads (21%) | catalogued as rs1307904737; called by muse, mutect2, varscan2
- OR2M4 | c.70C>T p.H24Y | Missense Mutation (SNP) | VAF 125/474 reads (26%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.52); catalogued as rs745730324; called by muse, mutect2, varscan2
- OR4C15 | c.453G>C p.M151I (on ENST00000314644; = p.M97I on NM_001001920.2) | Missense Mutation (SNP) | VAF 65/545 reads (12%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.025); catalogued as COSV58951556; called by muse, mutect2, varscan2
- OR5H14 | c.643C>A p.L215I | Missense Mutation (SNP) | VAF 46/207 reads (22%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.571); catalogued as COSV71193776; called by muse, mutect2, varscan2
- OSR2 | c.616C>A p.H206N | Missense Mutation (SNP) | VAF 82/372 reads (22%) | SIFT tolerated (0.36); PolyPhen benign (0.115); catalogued as COSV52559238; called by muse, mutect2, varscan2
- OTOGL | c.5933C>G p.P1978R (on ENST00000547103; = p.P1969R on NM_173591.4 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 112/496 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.723); catalogued as rs777681714; called by muse, mutect2
- P2RX7 | c.271G>A p.A91T | Missense Mutation (SNP) | VAF 26/447 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.899); catalogued as rs201451288; called by muse, mutect2
- PAPOLG | c.1970G>A p.R657K | Missense Mutation (SNP) | VAF 26/309 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.058); catalogued as COSV53184155; called by muse, mutect2
- PCDH11X | c.347C>T p.P116L | Missense Mutation (SNP) | VAF 33/402 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV53462647, COSV53483839; called by muse, mutect2
- PCDHA4 | c.123C>A p.H41Q | Missense Mutation (SNP) | VAF 215/687 reads (31%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.852); catalogued as COSV100793772; called by muse, mutect2, varscan2
- PDE1A | c.1355C>G p.T452S | Missense Mutation (SNP) | VAF 46/311 reads (15%) | SIFT tolerated (0.89); PolyPhen benign (0); catalogued as COSV59536418; called by muse, mutect2, varscan2
- PDE3A | c.1291C>A p.P431T | Missense Mutation (SNP) | VAF 73/366 reads (20%) | SIFT tolerated (0.76); PolyPhen possibly damaging (0.803); catalogued as rs375387597; called by muse, mutect2, varscan2
- PDE6C | c.1406C>A p.S469Y | Missense Mutation (SNP) | VAF 70/223 reads (31%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.804); catalogued as COSV65115050; called by muse, mutect2, varscan2
- PDPR | c.2354G>T p.W785L | Missense Mutation (SNP) | VAF 84/381 reads (22%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.845); catalogued as COSV55349327; called by muse, mutect2, varscan2
- PDZD2 | c.637G>T p.G213W | Missense Mutation (SNP) | VAF 145/629 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99223650; called by muse, mutect2, varscan2
- PEAK3 | c.579_580del p.H194Rfs*45 | Frame Shift Del (DEL) | VAF 94/475 reads (20%) | catalogued as rs1208761904; called by pindel, varscan2
- PGAP4 | c.1184G>T p.R395L | Missense Mutation (SNP) | VAF 43/340 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV66387423; called by muse, mutect2, varscan2
- PIK3CG | c.86C>A p.A29E | Missense Mutation (SNP) | VAF 112/450 reads (25%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.065); catalogued as COSV100783093; called by muse, mutect2, varscan2
- PKLR | c.336G>T p.M112I | Missense Mutation (SNP) | VAF 77/615 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV61360867; called by muse, mutect2, varscan2
- PNLIPRP2 | c.259C>G p.R87G | Missense Mutation (SNP) | VAF 71/478 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV53944274; called by muse, mutect2, varscan2
- PODN | c.838G>C p.V280L (on ENST00000395871; = p.V232L on NM_153703.5 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 58/541 reads (11%) | SIFT tolerated (0.31); PolyPhen benign (0.183); catalogued as COSV57014226; called by muse, mutect2, varscan2
- POLE | c.369G>T p.K123N | Missense Mutation (SNP) | VAF 98/511 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs1328407908; called by muse, mutect2, varscan2
- POTEE | c.2313G>T p.M771I | Missense Mutation (SNP) | VAF 105/699 reads (15%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs1278627588; called by muse, mutect2, varscan2
- PRKD2 | c.2301G>T p.M767I | Missense Mutation (SNP) | VAF 174/614 reads (28%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.922); catalogued as COSV52186419; called by muse, mutect2, varscan2
- PRRG3 | c.494G>T p.G165V | Missense Mutation (SNP) | VAF 86/808 reads (11%) | SIFT tolerated (0.06); PolyPhen benign (0); catalogued as COSV104427608, COSV64850625, COSV64850742; called by muse, varscan2
- PRSS56 | c.340G>A p.G114R | Missense Mutation (SNP) | VAF 113/688 reads (16%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.561); catalogued as rs894954030; called by muse, mutect2, varscan2
- PRUNE2 | c.1148C>A p.S383Y | Missense Mutation (SNP) | VAF 48/427 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV65038468; called by muse, mutect2, varscan2
- PTGIS | c.481G>T p.E161* | Nonsense Mutation (SNP) | VAF 33/427 reads (8%) | catalogued as COSV54837117, COSV54840735; called by muse, mutect2
- RALGPS1 | c.548A>G p.N183S | Missense Mutation (SNP) | VAF 42/345 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.72); catalogued as COSV52230370; called by muse, mutect2, varscan2
- REG1A | c.390C>A p.S130R | Missense Mutation (SNP) | VAF 74/380 reads (19%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.644); catalogued as rs748244874; called by muse, mutect2, varscan2
- REG1B | c.383C>A p.S128Y | Missense Mutation (SNP) | VAF 56/254 reads (22%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as COSV100521481; called by muse, mutect2, varscan2
- RFPL2 | c.1126G>T p.E376* | Nonsense Mutation (SNP) | VAF 36/177 reads (20%) | catalogued as COSV50709083; called by muse, mutect2, varscan2
- RGPD4 | c.3071A>T p.D1024V | Missense Mutation (SNP) | VAF 68/680 reads (10%) | SIFT deleterious (0); PolyPhen benign (0.379); catalogued as rs1178834144; called by muse, mutect2, varscan2
- RHBDF2 | c.1861G>T p.G621C | Missense Mutation (SNP) | VAF 57/441 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99166284; called by muse, mutect2, varscan2
- ROBO2 | c.3829G>A p.A1277T | Missense Mutation (SNP) | VAF 75/398 reads (19%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV59942113; called by muse, mutect2, varscan2
- RUVBL2 | c.475G>T p.G159C | Missense Mutation (SNP) | VAF 58/261 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99668898; called by muse, mutect2, varscan2
- SCAF11 | c.2894G>T p.R965L | Missense Mutation (SNP) | VAF 78/445 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV101014263; called by muse, mutect2, varscan2
- SCART1 | c.1756G>T p.D586Y | Missense Mutation (SNP) | VAF 151/803 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs775536404; called by muse, mutect2, varscan2
- SDK2 | c.5796C>A p.F1932L | Missense Mutation (SNP) | VAF 129/483 reads (27%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV66189478; called by muse, mutect2, varscan2
- SERHL2 | c.932C>T p.P311L | Missense Mutation (SNP) | VAF 52/318 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.017); catalogued as rs757388028; called by muse, mutect2
- SFXN2 | c.653G>T p.R218L | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.34); catalogued as COSV64012489; called by muse, mutect2, varscan2
- SHC3 | c.1626G>T p.K542N | Missense Mutation (SNP) | VAF 48/413 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65436898; called by muse, mutect2, varscan2
- SLC10A3 | c.217G>A p.V73M | Missense Mutation (SNP) | VAF 88/719 reads (12%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.736); catalogued as rs782728908; called by muse, mutect2, varscan2
- SLC19A3 | c.425A>G p.Y142C | Missense Mutation (SNP) | VAF 148/547 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs752695150; called by muse, mutect2, varscan2
- SLC30A3 | c.473G>T p.G158V | Missense Mutation (SNP) | VAF 132/504 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as rs1336385311; called by muse, mutect2, varscan2
- SLC38A4 | c.215C>A p.P72H | Missense Mutation (SNP) | VAF 79/405 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.873); catalogued as rs778035487, COSV99873014; called by mutect2, varscan2
- SOCS3 | c.212G>T p.R71L | Missense Mutation (SNP) | VAF 69/797 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100434539, COSV58270141; called by muse, mutect2
- STARD8 | c.1337C>A p.A446D | Missense Mutation (SNP) | VAF 136/756 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.184); catalogued as COSV52930739; called by muse, mutect2, varscan2
- TEP1 | c.1166G>T p.R389I | Missense Mutation (SNP) | VAF 82/378 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.202); catalogued as COSV53000237; called by muse, mutect2, varscan2
- TFAP2D | c.17C>A p.P6Q | Missense Mutation (SNP) | VAF 89/330 reads (27%) | SIFT tolerated, low confidence (0.07); PolyPhen probably damaging (0.993); catalogued as rs866860773; called by muse, varscan2
- THBS2 | c.380C>T p.T127I | Missense Mutation (SNP) | VAF 61/471 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0); catalogued as rs376392032; called by muse, mutect2, varscan2
- TKTL1 | c.795G>T p.E265D | Missense Mutation (SNP) | VAF 58/727 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.033); catalogued as COSV99474088; called by muse, mutect2
- TLR7 | c.1618C>A p.P540T | Missense Mutation (SNP) | VAF 89/590 reads (15%) | SIFT tolerated (0.38); PolyPhen benign (0.012); catalogued as rs367693931; called by muse, mutect2, varscan2
- TNRC18 | c.3434G>C p.R1145P | Missense Mutation (SNP) | VAF 100/662 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.003); catalogued as COSV68164208; called by muse, mutect2, varscan2
- TRIM10 | c.745G>T p.E249* | Nonsense Mutation (SNP) | VAF 82/403 reads (20%) | catalogued as COSV64994407, COSV64994494; called by muse, mutect2, varscan2
- TRIM27 | c.1304G>T p.R435L | Missense Mutation (SNP) | VAF 167/766 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.89); catalogued as COSV65873729; called by muse, mutect2, varscan2
- TRIM66 | c.164G>A p.C55Y | Missense Mutation (SNP) | VAF 104/376 reads (28%) | SIFT tolerated, low confidence (0.12); PolyPhen benign (0.229); catalogued as rs964481289; called by muse, mutect2, varscan2
- TROAP | c.119T>A p.V40E | Missense Mutation (SNP) | VAF 102/563 reads (18%) | SIFT tolerated (0.52); PolyPhen benign (0.014); catalogued as COSV99226879; called by muse, mutect2, varscan2
- TTN | c.26546C>T p.S8849L (on ENST00000591111; = p.S7922L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 100/547 reads (18%) | PolyPhen possibly damaging (0.683); catalogued as rs773637100, COSV60246912; called by muse, mutect2, varscan2
- TUBB8B | c.659C>A p.P220H | Missense Mutation (SNP) | VAF 82/578 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs1243476480; called by muse, varscan2
- USP39 | c.1423A>G p.I475V | Missense Mutation (SNP) | VAF 42/175 reads (24%) | SIFT tolerated (1); PolyPhen benign (0.027); catalogued as rs1350251931; called by muse, mutect2, varscan2
- VPS39 | c.72G>T p.W24C | Missense Mutation (SNP) | VAF 54/517 reads (10%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.969); catalogued as rs1020329181; called by muse, mutect2
- ZNF317 | c.1075del p.E359Rfs*51 | Frame Shift Del (DEL) | VAF 141/476 reads (30%) | catalogued as COSV56109326; called by mutect2, pindel, varscan2
- ZNF382 | c.863G>T p.R288I | Missense Mutation (SNP) | VAF 111/435 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.286); catalogued as COSV53088197, COSV53091934; called by muse, mutect2, varscan2
- ZNF568 | c.737G>T p.G246V | Missense Mutation (SNP) | VAF 34/408 reads (8%) | SIFT deleterious (0); PolyPhen possibly damaging (0.676); catalogued as COSV61742116; called by muse, mutect2
- ZNF707 | c.685G>T p.E229* | Nonsense Mutation (SNP) | VAF 201/1262 reads (16%) | catalogued as rs929816453, COSV100690678; called by muse, mutect2, varscan2
- ZNF804A | c.1069G>A p.G357R | Missense Mutation (SNP) | VAF 49/346 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.01); catalogued as COSV100165637; called by muse, mutect2, varscan2
- ZNF804A | c.1070G>T p.G357V | Missense Mutation (SNP) | VAF 50/328 reads (15%) | SIFT deleterious (0.05); PolyPhen benign (0.261); catalogued as COSV56439293; called by mutect2, varscan2
- ZNF98 | c.1090del p.H364Tfs*91 | Frame Shift Del (DEL) | VAF 102/370 reads (28%) | catalogued as COSV63339629; called by mutect2, varscan2
- ZSWIM2 | c.1173C>A p.N391K | Missense Mutation (SNP) | VAF 96/434 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); catalogued as rs571618049; called by mutect2, varscan2
- ABAT | c.155G>C p.G52A | Missense Mutation (SNP) | VAF 61/259 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- ABCA1 | c.4447G>A p.G1483R | Missense Mutation (SNP) | VAF 50/337 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ABCA2 | c.643G>T p.V215L (on ENST00000614293; = p.V185L on NM_001606.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/325 reads (10%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0.382); called by muse, mutect2, varscan2
- ABCC10 | c.3317A>T p.H1106L (on ENST00000372530 / NM_001198934.2; = p.H1078L on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 108/451 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- AC006059.2 | c.536C>A p.T179N | Missense Mutation (SNP) | VAF 139/494 reads (28%) | SIFT deleterious (0); PolyPhen benign (0.09); called by muse, mutect2, varscan2
- AC100868.1 | c.1677G>T p.L559F | Missense Mutation (SNP) | VAF 55/482 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- ADAMTS20 | c.1686G>A p.W562* | Nonsense Mutation (SNP) | VAF 114/555 reads (21%) | called by muse, mutect2, varscan2
- ADCY8 | c.3376del p.V1126Lfs*15 | Frame Shift Del (DEL) | VAF 112/703 reads (16%) | called by mutect2, pindel, varscan2
- ADD2 | c.214C>A p.Q72K | Missense Mutation (SNP) | VAF 94/358 reads (26%) | SIFT tolerated (0.05); PolyPhen benign (0.005); called by muse, varscan2
- ADGRG4 | c.9164G>T p.G3055V | Missense Mutation (SNP) | VAF 104/444 reads (23%) | SIFT deleterious (0); PolyPhen possibly damaging (0.831); called by muse, mutect2, varscan2
- ADGRV1 | c.12903G>T p.W4301C | Missense Mutation (SNP) | VAF 67/309 reads (22%) | SIFT tolerated (0.44); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ADPRS | c.613G>T p.E205* | Nonsense Mutation (SNP) | VAF 93/573 reads (16%) | called by muse, mutect2, varscan2
- AFAP1 | c.860G>T p.G287V | Missense Mutation (SNP) | VAF 30/222 reads (14%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.981); called by muse, mutect2, varscan2
- AGAP4 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 67/317 reads (21%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.77); called by muse, mutect2, varscan2
- AHI1 | c.3262T>A p.W1088R | Missense Mutation (SNP) | VAF 44/488 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- AJAP1 | c.809G>C p.R270T | Missense Mutation (SNP) | VAF 44/433 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- AK9 | c.2200G>T p.E734* | Nonsense Mutation (SNP) | VAF 42/255 reads (16%) | called by muse, mutect2, varscan2
- ALMS1 | c.3436C>T p.Q1146* | Nonsense Mutation (SNP) | VAF 32/516 reads (6%) | called by muse, mutect2
- AMER1 | c.2453G>T p.G818V | Missense Mutation (SNP) | VAF 107/648 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- ANK2 | c.11405G>T p.S3802I | Missense Mutation (SNP) | VAF 91/455 reads (20%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- ANKRD34B | c.564A>C p.E188D | Missense Mutation (SNP) | VAF 71/460 reads (15%) | SIFT tolerated (0.5); PolyPhen benign (0); called by muse, mutect2, varscan2
- ANO2 | c.1906T>A p.F636I (on ENST00000356134 / NM_001278597.3; = p.F640I on NM_001278596.3) | Missense Mutation (SNP) | VAF 66/323 reads (20%) | SIFT tolerated (0.09); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- ANO3 | c.2719T>C p.W907R | Missense Mutation (SNP) | VAF 100/418 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- APBA2 | c.189C>A p.C63* | Nonsense Mutation (SNP) | VAF 158/773 reads (20%) | called by muse, mutect2, varscan2
- APOB | c.9755C>G p.T3252S | Missense Mutation (SNP) | VAF 50/452 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.098); called by muse, mutect2, varscan2
- AQR | c.1759G>C p.V587L | Missense Mutation (SNP) | VAF 30/353 reads (8%) | SIFT tolerated (0.56); PolyPhen benign (0.013); called by muse, mutect2
- ARAP3 | c.2369G>T p.S790I | Missense Mutation (SNP) | VAF 161/515 reads (31%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- ARHGAP20 | c.1120G>C p.D374H | Missense Mutation (SNP) | VAF 34/260 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- ARL13A | c.188A>T p.D63V | Missense Mutation (SNP) | VAF 38/421 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.925); called by muse, mutect2
- ARMC10 | c.1029C>G p.I343M | Missense Mutation (SNP) | VAF 32/209 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ARPP21 | c.445T>A p.L149I | Missense Mutation (SNP) | VAF 80/317 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- ASCC3 | c.3934G>C p.A1312P | Missense Mutation (SNP) | VAF 33/471 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2
- ASTN1 | c.1086C>A p.Y362* | Nonsense Mutation (SNP) | VAF 36/438 reads (8%) | called by muse, mutect2
- ASXL3 | c.1447C>G p.L483V | Missense Mutation (SNP) | VAF 79/431 reads (18%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- ATL3 | c.326G>A p.R109K | Missense Mutation (SNP) | VAF 52/589 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.147); called by muse, mutect2
- ATP2B3 | c.3642C>A p.H1214Q | Missense Mutation (SNP) | VAF 87/427 reads (20%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.102); called by muse, mutect2, varscan2
- ATP7A | c.300G>T p.W100C | Missense Mutation (SNP) | VAF 37/435 reads (9%) | SIFT tolerated (0.29); PolyPhen benign (0.007); called by muse, mutect2
- ATP7A | c.4429G>A p.V1477I | Missense Mutation (SNP) | VAF 40/660 reads (6%) | SIFT tolerated (0.53); PolyPhen benign (0.001); called by muse, mutect2
- AVIL | c.1619A>G p.N540S | Missense Mutation (SNP) | VAF 129/548 reads (24%) | SIFT tolerated (0.35); PolyPhen possibly damaging (0.588); called by muse, mutect2, varscan2
- BACH2 | c.2497G>T p.D833Y | Missense Mutation (SNP) | VAF 71/308 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); called by muse, mutect2, varscan2
- BARX2 | c.602C>G p.T201R | Missense Mutation (SNP) | VAF 71/292 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.933); called by muse, mutect2, varscan2
- BBOX1 | c.580T>A p.Y194N | Missense Mutation (SNP) | VAF 75/255 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BCAS1 | c.557C>T p.S186F | Missense Mutation (SNP) | VAF 75/437 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); called by muse, mutect2, varscan2
- BCL2L12 | c.866G>T p.R289L | Missense Mutation (SNP) | VAF 58/695 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- BCORL1 | c.3987G>T p.R1329S | Missense Mutation (SNP) | VAF 128/589 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- BECN2 | c.26A>C p.Q9P | Missense Mutation (SNP) | VAF 45/440 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.685); called by muse, mutect2, varscan2
- BNC1 | c.1675C>A p.H559N | Missense Mutation (SNP) | VAF 71/546 reads (13%) | SIFT tolerated (0.45); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- BOD1L2 | c.31G>T p.G11C | Missense Mutation (SNP) | VAF 145/548 reads (26%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.561); called by muse, mutect2, varscan2
- BRD1 | c.832G>T p.G278C | Missense Mutation (SNP) | VAF 72/551 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- BRDT | c.1764G>A p.M588I | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.028); called by muse, mutect2
- BTN3A1 | c.1489G>T p.V497F | Missense Mutation (SNP) | VAF 34/341 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.018); called by muse, mutect2
- BX276092.9 | c.1485G>T p.Q495H | Missense Mutation (SNP) | VAF 64/374 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.814); called by muse, mutect2, varscan2
- C1QL3 | c.438C>G p.D146E | Missense Mutation (SNP) | VAF 111/540 reads (21%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- C2orf81 | c.1048G>T p.D350Y | Missense Mutation (SNP) | VAF 86/601 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- C3 | c.4915G>T p.D1639Y | Missense Mutation (SNP) | VAF 66/434 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- C8B | c.1570A>T p.I524F | Missense Mutation (SNP) | VAF 34/228 reads (15%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.945); called by muse, mutect2, varscan2
- CATSPERZ | c.553T>C p.Y185H | Missense Mutation (SNP) | VAF 43/409 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- CBARP | c.855G>T p.K285N (on ENST00000382477; = p.K265N on NM_152769.3) | Missense Mutation (SNP) | VAF 143/529 reads (27%) | SIFT tolerated (0.18); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- CCDC22 | c.605G>A p.R202K | Missense Mutation (SNP) | VAF 163/818 reads (20%) | SIFT tolerated (0.78); PolyPhen possibly damaging (0.527); called by muse, mutect2, varscan2
- CD300LG | c.153C>A p.C51* | Nonsense Mutation (SNP) | VAF 48/490 reads (10%) | called by muse, mutect2
- CDH11 | c.1672G>T p.G558* | Nonsense Mutation (SNP) | VAF 89/437 reads (20%) | called by muse, mutect2, varscan2
- CDH12 | c.2369del p.P790Lfs*55 | Frame Shift Del (DEL) | VAF 48/269 reads (18%) | called by mutect2, pindel, varscan2
- CDH6 | c.819C>A p.Y273* | Nonsense Mutation (SNP) | VAF 52/306 reads (17%) | called by muse, mutect2, varscan2
- CDH7 | c.1556T>C p.F519S | Missense Mutation (SNP) | VAF 72/366 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- CDH8 | c.1847C>A p.P616Q | Missense Mutation (SNP) | VAF 101/493 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); called by muse, mutect2, varscan2
- CDH8 | c.917G>T p.G306V | Missense Mutation (SNP) | VAF 100/467 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- CEACAM20 | c.1571A>G p.E524G | Missense Mutation (SNP) | VAF 50/518 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2
- CEACAM21 | c.334G>T p.V112F | Missense Mutation (SNP) | VAF 60/730 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2
- CEP126 | c.1396C>G p.P466A | Missense Mutation (SNP) | VAF 36/417 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.315); called by muse, mutect2
- CEP170 | c.2871G>C p.K957N | Missense Mutation (SNP) | VAF 34/469 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.384); called by muse, mutect2
- CEP55 | c.31A>T p.K11* | Nonsense Mutation (SNP) | VAF 59/239 reads (25%) | called by muse, mutect2, varscan2
- CHCHD4 | c.240G>T p.E80D (on ENST00000396914 / NM_001098502.2; = p.E93D on NM_144636.3) | Missense Mutation (SNP) | VAF 118/478 reads (25%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.905); called by muse, mutect2, varscan2
- CHD7 | c.7612G>T p.D2538Y | Missense Mutation (SNP) | VAF 60/312 reads (19%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- CHRFAM7A | c.946G>A p.V316M | Missense Mutation (SNP) | VAF 88/502 reads (18%) | SIFT tolerated (0.29); PolyPhen benign (0.043); called by muse, mutect2, varscan2
- CNTN2 | c.2141C>A p.P714H | Missense Mutation (SNP) | VAF 123/496 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CNTNAP4 | c.2842G>A p.A948T | Missense Mutation (SNP) | VAF 41/346 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- COL12A1 | c.1798G>T p.E600* | Nonsense Mutation (SNP) | VAF 50/458 reads (11%) | called by muse, mutect2, varscan2
- COL14A1 | c.4591_4592delinsA p.L1531Ifs*41 | Frame Shift Del (DEL) | VAF 182/748 reads (24%) | called by pindel, varscan2*
- COL19A1 | c.3385C>G p.L1129V | Missense Mutation (SNP) | VAF 30/378 reads (8%) | SIFT tolerated (0.31); PolyPhen benign (0.039); called by muse, mutect2
- COL5A2 | c.1051G>T p.G351C | Missense Mutation (SNP) | VAF 52/388 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- COL6A3 | c.4254G>T p.K1418N | Missense Mutation (SNP) | VAF 76/471 reads (16%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- COL7A1 | c.7739G>T p.R2580L | Missense Mutation (SNP) | VAF 59/501 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- COQ2 | c.1177G>T p.V393F | Missense Mutation (SNP) | VAF 64/323 reads (20%) | SIFT tolerated (0.11); PolyPhen benign (0.206); called by muse, mutect2, varscan2
- CRB2 | c.3058G>T p.G1020C | Missense Mutation (SNP) | VAF 127/596 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- CSF2RB | c.915C>A p.H305Q | Missense Mutation (SNP) | VAF 185/826 reads (22%) | SIFT tolerated (0.14); PolyPhen benign (0.341); called by muse, mutect2, varscan2
- CSH1 | c.124C>T p.Q42* | Nonsense Mutation (SNP) | VAF 65/298 reads (22%) | called by muse, mutect2, varscan2
- CSMD2 | c.2792C>A p.S931Y | Missense Mutation (SNP) | VAF 53/395 reads (13%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.934); called by muse, mutect2, varscan2
- CSMD3 | c.3188G>C p.C1063S (on ENST00000297405 / NM_001363185.1; = p.C959S on NM_052900.3) | Missense Mutation (SNP) | VAF 106/308 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.853); called by muse, mutect2, varscan2
- CYP2C19 | c.1409C>A p.T470N | Missense Mutation (SNP) | VAF 94/322 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.134); called by mutect2, varscan2
- DAOA | c.449C>A p.T150N | Missense Mutation (SNP) | VAF 28/191 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.381); called by mutect2, varscan2
- DCAF4L2 | c.290C>A p.S97Y | Missense Mutation (SNP) | VAF 88/502 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.197); called by muse, mutect2, varscan2
- DCHS1 | c.9415G>T p.G3139C | Missense Mutation (SNP) | VAF 106/474 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- DDX3X | c.1534G>A p.V512I (on ENST00000399959; = p.V513I on NM_001356.5) | Missense Mutation (SNP) | VAF 53/367 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.422); called by muse, mutect2, varscan2
- DIAPH2 | c.1724C>G p.A575G | Missense Mutation (SNP) | VAF 66/718 reads (9%) | SIFT tolerated (0.43); PolyPhen benign (0); called by muse, mutect2
- DIP2A | c.3599G>T p.G1200V | Missense Mutation (SNP) | VAF 46/436 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- DNAH11 | c.5599G>T p.V1867L | Missense Mutation (SNP) | VAF 51/272 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- DNAH17 | c.9414G>T p.E3138D | Missense Mutation (SNP) | VAF 122/507 reads (24%) | SIFT tolerated (0.38); PolyPhen possibly damaging (0.492); called by muse, mutect2, varscan2
- DNER | c.514A>T p.T172S | Missense Mutation (SNP) | VAF 81/452 reads (18%) | SIFT tolerated (0.21); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- DPYS | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 60/394 reads (15%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); called by muse, varscan2
- DYNC2I1 | c.1982A>T p.H661L | Missense Mutation (SNP) | VAF 76/413 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.447); called by muse, mutect2, varscan2
- DYSF | c.2578C>A p.L860I | Missense Mutation (SNP) | VAF 98/412 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EBF3 | c.1620C>A p.S540R | Missense Mutation (SNP) | VAF 87/575 reads (15%) | SIFT deleterious (0.01); PolyPhen benign (0.145); called by muse, mutect2, varscan2
- ECM1 | c.620G>T p.G207V | Missense Mutation (SNP) | VAF 206/592 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EDN3 | c.227C>A p.P76H | Missense Mutation (SNP) | VAF 24/720 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); called by muse, mutect2
- ELP3 | c.493G>T p.V165L | Missense Mutation (SNP) | VAF 41/318 reads (13%) | SIFT deleterious (0.05); PolyPhen benign (0.068); called by muse, mutect2, varscan2
- EMSY | c.815A>G p.N272S | Missense Mutation (SNP) | VAF 55/240 reads (23%) | SIFT tolerated (0.38); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- ENOX1 | c.487G>A p.E163K | Missense Mutation (SNP) | VAF 24/391 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.134); called by muse, mutect2
- ENOX2 | c.562C>A p.L188M (on ENST00000338144 / NM_001382520.1; = p.L159M on NM_006375.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 46/460 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); called by muse, varscan2
- EPB41L3 | c.621G>T p.L207F | Missense Mutation (SNP) | VAF 46/270 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- EPS8L3 | c.149C>A p.A50D | Missense Mutation (SNP) | VAF 47/470 reads (10%) | SIFT deleterious (0); PolyPhen possibly damaging (0.876); called by muse, mutect2, varscan2
- ERBB4 | c.1124+1del p.X375_splice | Splice Site (DEL) | VAF 30/180 reads (17%) | called by mutect2, pindel, varscan2
- EXOC2 | c.1773G>C p.L591F | Missense Mutation (SNP) | VAF 24/302 reads (8%) | SIFT tolerated (0.28); PolyPhen benign (0.134); called by muse, mutect2
- EXOC8 | c.125A>T p.Q42L | Missense Mutation (SNP) | VAF 192/647 reads (30%) | SIFT tolerated (1); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- EXTL3 | c.1924G>T p.G642* | Nonsense Mutation (SNP) | VAF 98/525 reads (19%) | called by muse, mutect2, varscan2
- EZHIP | c.698C>A p.P233H | Missense Mutation (SNP) | VAF 116/622 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, mutect2, varscan2
- FAM117A | c.376T>A p.S126T | Missense Mutation (SNP) | VAF 36/300 reads (12%) | SIFT tolerated (0.15); PolyPhen possibly damaging (0.825); called by muse, mutect2, varscan2
- FAM47A | c.41G>T p.G14V | Missense Mutation (SNP) | VAF 82/547 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); called by muse, mutect2, varscan2
- FAM83B | c.1366C>A p.L456I | Missense Mutation (SNP) | VAF 57/469 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- FAM83E | c.61del p.A21Pfs*19 | Frame Shift Del (DEL) | VAF 134/550 reads (24%) | called by mutect2, pindel, varscan2
- FANCM | c.4279G>T p.V1427F | Missense Mutation (SNP) | VAF 40/330 reads (12%) | SIFT tolerated (0.08); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- FBH1 | c.3074G>T p.R1025L (on ENST00000362091 / NM_178150.3; = p.R1076L on NM_032807.4) | Missense Mutation (SNP) | VAF 101/544 reads (19%) | SIFT tolerated (0.65); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- FBXO42 | c.1600A>G p.T534A | Missense Mutation (SNP) | VAF 59/491 reads (12%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.054); called by muse, mutect2, varscan2
- FCAR | c.825dup p.G276Rfs*18 | Frame Shift Ins (INS) | VAF 162/663 reads (24%) | called by mutect2, pindel, varscan2
- FGD1 | c.1489G>T p.E497* | Nonsense Mutation (SNP) | VAF 67/475 reads (14%) | called by muse, mutect2, varscan2
- FGF17 | c.5G>T p.G2V | Missense Mutation (SNP) | VAF 93/684 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- FIGN | c.1703A>G p.H568R | Missense Mutation (SNP) | VAF 84/498 reads (17%) | SIFT tolerated (0.46); PolyPhen benign (0.104); called by muse, mutect2, varscan2
- FMN1 | c.613T>C p.S205P | Missense Mutation (SNP) | VAF 87/378 reads (23%) | SIFT tolerated, low confidence (0.1); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- FMR1 | c.1631G>T p.R544I | Missense Mutation (SNP) | VAF 34/471 reads (7%) | SIFT tolerated, low confidence (0.06); PolyPhen possibly damaging (0.661); called by muse, mutect2
- FN3K | c.297A>T p.Q99H | Missense Mutation (SNP) | VAF 40/238 reads (17%) | SIFT tolerated (1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- FOXG1 | c.412G>C p.A138P | Missense Mutation (SNP) | VAF 91/561 reads (16%) | SIFT tolerated, low confidence (0.16); PolyPhen benign (0); called by muse, mutect2, varscan2
- FREM3 | c.844G>T p.A282S | Missense Mutation (SNP) | VAF 114/535 reads (21%) | SIFT tolerated (0.68); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- FSIP2 | c.15205C>A p.Q5069K | Missense Mutation (SNP) | VAF 37/254 reads (15%) | SIFT deleterious (0); PolyPhen benign (0.095); called by muse, mutect2, varscan2
- GAB4 | c.977C>A p.A326D | Missense Mutation (SNP) | VAF 38/492 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.334); called by muse, mutect2
- GABRA6 | c.503A>T p.H168L | Missense Mutation (SNP) | VAF 51/269 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GABRD | c.122T>A p.L41H | Missense Mutation (SNP) | VAF 114/452 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- GCSAML | c.140G>T p.S47I | Missense Mutation (SNP) | VAF 52/305 reads (17%) | SIFT tolerated (0.05); PolyPhen benign (0.04); called by muse, mutect2, varscan2
- GJD4 | c.277A>T p.S93C | Missense Mutation (SNP) | VAF 128/725 reads (18%) | SIFT deleterious (0); PolyPhen benign (0.123); called by muse, mutect2, varscan2
- GLMN | c.1099G>T p.G367C | Missense Mutation (SNP) | VAF 58/316 reads (18%) | SIFT deleterious (0.01); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- GLOD5 | c.39G>T p.M13I | Missense Mutation (SNP) | VAF 82/540 reads (15%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.099); called by muse, mutect2, varscan2
- GLYATL1B | c.764T>A p.L255Q | Missense Mutation (SNP) | VAF 47/438 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- GPATCH2 | c.114G>C p.E38D | Missense Mutation (SNP) | VAF 32/447 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); called by muse, mutect2
- GPLD1 | c.1289A>T p.D430V | Missense Mutation (SNP) | VAF 42/486 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); called by muse, mutect2
- GPR156 | c.499G>T p.G167W | Missense Mutation (SNP) | VAF 69/284 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GPR34 | c.776G>T p.G259V | Missense Mutation (SNP) | VAF 53/500 reads (11%) | SIFT tolerated (0.17); PolyPhen benign (0.065); called by muse, mutect2, varscan2
- GPRASP1 | c.145G>A p.G49R | Missense Mutation (SNP) | VAF 58/651 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.132); called by muse, mutect2
- GRID2 | c.1633G>A p.V545M | Missense Mutation (SNP) | VAF 97/420 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- GRID2IP | c.763C>A p.P255T | Missense Mutation (SNP) | VAF 84/534 reads (16%) | SIFT tolerated (0.39); PolyPhen benign (0.107); called by muse, varscan2
- GRK1 | c.851A>T p.E284V | Missense Mutation (SNP) | VAF 35/307 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.797); called by muse, mutect2, varscan2
- GTF2A2 | c.153G>C p.R51S | Missense Mutation (SNP) | VAF 63/309 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.069); called by muse, mutect2, varscan2
- GTF3C1 | c.5338_5355del p.F1780_Q1785del | In Frame Del (DEL) | VAF 50/412 reads (12%) | called by mutect2, pindel, varscan2
- HAL | c.376C>G p.L126V | Missense Mutation (SNP) | VAF 44/434 reads (10%) | SIFT tolerated (0.29); PolyPhen benign (0.116); called by muse, mutect2, varscan2
- HAUS7 | c.577G>C p.D193H | Missense Mutation (SNP) | VAF 76/680 reads (11%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.896); called by muse, mutect2, varscan2
- HEATR5B | c.1061G>T p.R354I | Missense Mutation (SNP) | VAF 36/343 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, varscan2
- HFM1 | c.3980T>A p.V1327D | Missense Mutation (SNP) | VAF 28/199 reads (14%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.058); called by muse, mutect2, varscan2
- HNRNPCL1 | c.613G>C p.E205Q | Missense Mutation (SNP) | VAF 61/1014 reads (6%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.724); called by muse, mutect2
- HNRNPH2 | c.947G>T p.R316I | Missense Mutation (SNP) | VAF 70/727 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.792); called by muse, mutect2
- HRG | c.212T>C p.L71S | Missense Mutation (SNP) | VAF 69/327 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- HTR2A | c.573G>T p.K191N | Missense Mutation (SNP) | VAF 35/317 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.888); called by mutect2, varscan2
- HYDIN | c.14149T>A p.W4717R | Missense Mutation (SNP) | VAF 20/336 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.834); called by muse, mutect2
- IGHV3-16 | c.89T>A p.L30* | Nonsense Mutation (SNP) | VAF 86/490 reads (18%) | called by muse, varscan2
- IL13RA1 | c.88G>C p.E30Q | Missense Mutation (SNP) | VAF 24/356 reads (7%) | SIFT deleterious (0.02); PolyPhen benign (0.255); called by muse, mutect2
- IL4R | c.2341G>T p.A781S | Missense Mutation (SNP) | VAF 60/638 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.142); called by muse, mutect2
- INPP5B | c.1201del p.E401Sfs*19 (on ENST00000373023; = p.E321Sfs*19 on NM_005540.3 and 3 other RefSeq transcripts) | Frame Shift Del (DEL) | VAF 35/345 reads (10%) | called by mutect2, pindel*
- INTS2 | c.1723G>A p.D575N | Missense Mutation (SNP) | VAF 27/200 reads (14%) | SIFT tolerated (0.48); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- ISL1 | c.974G>T p.G325V | Missense Mutation (SNP) | VAF 65/486 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.382); called by mutect2, varscan2
- ITGA4 | c.1156G>T p.V386F | Missense Mutation (SNP) | VAF 54/291 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); called by muse, mutect2, varscan2
- ITIH2 | c.707G>T p.G236V | Missense Mutation (SNP) | VAF 33/319 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.927); called by muse, mutect2, varscan2
- ITIH5 | c.1927A>T p.M643L | Missense Mutation (SNP) | VAF 78/548 reads (14%) | SIFT tolerated (0.27); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- ITIH5 | c.883A>T p.N295Y | Missense Mutation (SNP) | VAF 55/362 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- ITPR2 | c.530T>C p.V177A | Missense Mutation (SNP) | VAF 32/291 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.973); called by muse, mutect2, varscan2
- KBTBD6 | c.1016G>T p.G339V | Missense Mutation (SNP) | VAF 36/347 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- KCNC2 | c.1262T>A p.F421Y | Missense Mutation (SNP) | VAF 118/505 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KCNN3 | c.1842A>T p.K614N (on ENST00000618040 / NM_001204087.1; = p.K599N on NM_002249.6) | Missense Mutation (SNP) | VAF 91/339 reads (27%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.809); called by muse, mutect2, varscan2
- KCTD11 | c.421C>T p.H141Y (on ENST00000333751 / NM_001363642.1; = p.H102Y on NM_001002914.2) | Missense Mutation (SNP) | VAF 178/590 reads (30%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.703); called by muse, mutect2, varscan2
- KDR | c.2439G>T p.L813F | Missense Mutation (SNP) | VAF 123/496 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.575); called by muse, mutect2, varscan2
- KERA | c.478G>T p.G160W | Missense Mutation (SNP) | VAF 91/479 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- KIF17 | c.207C>A p.N69K | Missense Mutation (SNP) | VAF 63/432 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.449); called by muse, mutect2, varscan2
- KIRREL3 | c.385G>T p.A129S | Missense Mutation (SNP) | VAF 61/530 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- KLHL31 | c.1442G>T p.R481L | Missense Mutation (SNP) | VAF 143/523 reads (27%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- KLK6 | c.639G>T p.W213C | Missense Mutation (SNP) | VAF 64/671 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- KRT2 | c.1298A>T p.H433L | Missense Mutation (SNP) | VAF 76/422 reads (18%) | SIFT tolerated (1); PolyPhen benign (0.356); called by muse, mutect2, varscan2
- KRTAP20-1 | c.12C>A p.Y4* | Nonsense Mutation (SNP) | VAF 31/319 reads (10%) | called by muse, mutect2
- KRTAP5-5 | c.571C>A p.P191T | Missense Mutation (SNP) | VAF 166/540 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.308); called by muse, varscan2
- LAMA2 | c.7665C>A p.S2555R | Missense Mutation (SNP) | VAF 51/451 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LHX2 | c.811A>T p.T271S | Missense Mutation (SNP) | VAF 69/513 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- LILRB2 | c.1684T>G p.Y562D | Missense Mutation (SNP) | VAF 64/610 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- LPIN1 | c.1027G>T p.V343L | Missense Mutation (SNP) | VAF 46/440 reads (10%) | SIFT tolerated (0.38); PolyPhen benign (0.001); called by muse, mutect2
- LRP12 | c.1785G>T p.M595I | Missense Mutation (SNP) | VAF 88/444 reads (20%) | SIFT tolerated (0.5); PolyPhen benign (0); called by mutect2, varscan2
- LRP1B | c.11096G>T p.C3699F | Missense Mutation (SNP) | VAF 71/479 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- LRRC4B | c.181T>C p.C61R | Missense Mutation (SNP) | VAF 92/811 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- LRRC7 | c.42C>A p.Y14* | Nonsense Mutation (SNP) | VAF 85/415 reads (20%) | called by muse, mutect2, varscan2
- LYPLAL1 | c.271C>T p.L91F | Missense Mutation (SNP) | VAF 36/437 reads (8%) | SIFT tolerated (0.16); PolyPhen benign (0.309); called by muse, mutect2
- MACF1 | c.21557G>C p.R7186P (on ENST00000372915; = p.R5231P on NM_012090.5) | Missense Mutation (SNP) | VAF 74/296 reads (25%) | called by muse, mutect2, varscan2
- MAGEA12 | c.907C>A p.P303T | Missense Mutation (SNP) | VAF 26/348 reads (7%) | SIFT tolerated (0.4); PolyPhen benign (0.055); called by muse, mutect2
- MAP3K2 | c.1522C>T p.L508F | Missense Mutation (SNP) | VAF 46/606 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.714); called by muse, mutect2
- MBD3L3 | c.471G>T p.M157I | Missense Mutation (SNP) | VAF 106/1274 reads (8%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2
- MBD5 | c.2504C>A p.T835K | Missense Mutation (SNP) | VAF 28/578 reads (5%) | SIFT deleterious (0.01); PolyPhen benign (0.26); called by muse, mutect2
- MED12 | c.4794G>T p.M1598I | Missense Mutation (SNP) | VAF 85/570 reads (15%) | SIFT tolerated (0.1); PolyPhen benign (0.122); called by muse, mutect2, varscan2
- MEI4 | c.627G>T p.W209C | Missense Mutation (SNP) | VAF 38/367 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.168); called by muse, mutect2, varscan2
- MPHOSPH8 | c.967G>C p.D323H | Missense Mutation (SNP) | VAF 74/412 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.635); called by muse, mutect2, varscan2
- MRC1 | c.1432T>C p.C478R | Missense Mutation (SNP) | VAF 75/507 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MRC1 | c.2719G>T p.G907W | Missense Mutation (SNP) | VAF 57/349 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- MROH2A | c.383C>T p.S128F | Missense Mutation (SNP) | VAF 45/290 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.397); called by muse, mutect2, varscan2
- MROH5 | c.1866G>T p.L622F | Missense Mutation (SNP) | VAF 48/562 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (1); called by muse, mutect2
- MRPL28 | c.631G>T p.A211S | Missense Mutation (SNP) | VAF 45/353 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- MS4A18 | c.394C>A p.Q132K | Missense Mutation (SNP) | VAF 43/420 reads (10%) | SIFT deleterious (0.04); PolyPhen benign (0.045); called by muse, mutect2, varscan2
- MS4A5 | c.46C>A p.P16T | Missense Mutation (SNP) | VAF 37/449 reads (8%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.966); called by muse, mutect2
- MTMR8 | c.315A>T p.L105F | Missense Mutation (SNP) | VAF 32/284 reads (11%) | SIFT tolerated (0.14); PolyPhen benign (0.424); called by muse, mutect2, varscan2
- MUC12 | c.13292C>A p.P4431H (on ENST00000379442; = p.P4288H on NM_001164462.1) | Missense Mutation (SNP) | VAF 42/371 reads (11%) | SIFT deleterious (0); called by muse, mutect2, varscan2
- MXRA5 | c.444C>G p.N148K | Missense Mutation (SNP) | VAF 110/577 reads (19%) | SIFT tolerated (0.27); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- MYCBP2 | c.3111_3114del p.A1038Hfs*10 (on ENST00000357337; = p.A1076Hfs*10 on NM_015057.5) | Frame Shift Del (DEL) | VAF 36/390 reads (9%) | called by mutect2, pindel
- MYH13 | c.3194T>A p.M1065K | Missense Mutation (SNP) | VAF 84/374 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.031); called by muse, mutect2, varscan2
- MYH13 | c.2347G>T p.E783* | Nonsense Mutation (SNP) | VAF 93/435 reads (21%) | called by muse, mutect2, varscan2
- MYH14 | c.2607G>T p.E869D | Missense Mutation (SNP) | VAF 51/615 reads (8%) | SIFT tolerated (0.15); PolyPhen benign (0.001); called by muse, mutect2
- MYH14 | c.2608G>T p.V870L | Missense Mutation (SNP) | VAF 50/614 reads (8%) | SIFT tolerated (0.2); PolyPhen benign (0); called by muse, mutect2
- MYH7 | c.5291T>G p.M1764R | Missense Mutation (SNP) | VAF 70/404 reads (17%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.906); called by muse, mutect2, varscan2
- MYH7 | c.2042C>T p.P681L | Missense Mutation (SNP) | VAF 62/274 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, varscan2
- MYH7B | c.2600G>T p.R867L | Missense Mutation (SNP) | VAF 51/358 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MYO1B | c.1140G>T p.K380N | Missense Mutation (SNP) | VAF 51/305 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.257); called by muse, mutect2, varscan2
- MYO7B | c.2603G>C p.G868A | Missense Mutation (SNP) | VAF 58/576 reads (10%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.966); called by muse, mutect2, varscan2
- NCAN | c.1883C>G p.P628R | Missense Mutation (SNP) | VAF 46/680 reads (7%) | SIFT tolerated (0.61); PolyPhen benign (0.017); called by muse, mutect2
- NCKAP5 | c.345G>T p.M115I | Missense Mutation (SNP) | VAF 53/296 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.82); called by muse, mutect2, varscan2
- NEK1 | c.1444G>T p.G482* | Nonsense Mutation (SNP) | VAF 54/204 reads (26%) | called by muse, mutect2, varscan2
- NEURL1 | c.859C>A p.P287T | Missense Mutation (SNP) | VAF 82/323 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.335); called by muse, mutect2, varscan2
- NFATC2 | c.1788G>T p.M596I | Missense Mutation (SNP) | VAF 60/456 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.995); called by muse, mutect2, varscan2
- NLRP12 | c.1719C>A p.S573R | Missense Mutation (SNP) | VAF 44/455 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.296); called by muse, mutect2, varscan2
- NLRP5 | c.334C>A p.L112I | Missense Mutation (SNP) | VAF 42/558 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.996); called by muse, mutect2
- NOS1 | c.4045G>A p.G1349S | Missense Mutation (SNP) | VAF 113/585 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- NOS1 | c.555G>T p.Q185H | Missense Mutation (SNP) | VAF 129/553 reads (23%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.039); called by muse, mutect2, varscan2
- NOS1 | c.554A>T p.Q185L | Missense Mutation (SNP) | VAF 130/552 reads (24%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); called by muse, mutect2, varscan2
- NOTCH4 | c.4573G>C p.V1525L | Missense Mutation (SNP) | VAF 52/444 reads (12%) | SIFT tolerated (0.27); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- NOVA2 | c.677C>A p.P226H | Missense Mutation (SNP) | VAF 80/651 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- NOX1 | c.22C>A p.H8N | Missense Mutation (SNP) | VAF 32/530 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.005); called by muse, mutect2
- NPTX2 | c.851G>C p.W284S | Missense Mutation (SNP) | VAF 58/454 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.977); called by muse, mutect2, varscan2
- NR4A1 | c.1427C>T p.A476V | Missense Mutation (SNP) | VAF 65/610 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- NRXN1 | c.1438G>T p.D480Y | Missense Mutation (SNP) | VAF 50/426 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); called by mutect2, varscan2
- NSMF | c.1575C>G p.D525E (on ENST00000371475 / NM_001130969.3; = p.D523E on NM_015537.4) | Missense Mutation (SNP) | VAF 38/344 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.987); called by muse, mutect2, varscan2
- NYX | c.853C>A p.L285M | Missense Mutation (SNP) | VAF 148/877 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- OGFOD3 | c.659G>T p.R220L | Missense Mutation (SNP) | VAF 49/459 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.165); called by muse, mutect2, varscan2
- OR10Z1 | c.29G>T p.R10M | Missense Mutation (SNP) | VAF 91/339 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.012); called by muse, mutect2, varscan2
- OR13D1 | c.163C>T p.L55F | Missense Mutation (SNP) | VAF 69/463 reads (15%) | SIFT deleterious (0.02); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- OR14C36 | c.734T>A p.V245E | Missense Mutation (SNP) | VAF 133/454 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- OR14J1 | c.889G>T p.A297S | Missense Mutation (SNP) | VAF 85/389 reads (22%) | SIFT tolerated (0.23); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- OR56A5 | c.32C>T p.P11L | Missense Mutation (SNP) | VAF 63/273 reads (23%) | SIFT tolerated (0.14); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR5B12 | c.308T>A p.V103E | Missense Mutation (SNP) | VAF 90/493 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.467); called by muse, mutect2, varscan2
- OR5D14 | c.323C>G p.T108S | Missense Mutation (SNP) | VAF 96/438 reads (22%) | SIFT tolerated (0.09); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- OR5K3 | c.85G>T p.V29L | Missense Mutation (SNP) | VAF 65/325 reads (20%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- OR6B1 | c.76G>A p.A26T | Missense Mutation (SNP) | VAF 88/399 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- OR6C3 | c.241del p.A81Qfs*26 | Frame Shift Del (DEL) | VAF 94/606 reads (16%) | called by mutect2, pindel, varscan2
- OR6S1 | c.434G>T p.R145L | Missense Mutation (SNP) | VAF 77/372 reads (21%) | SIFT tolerated (1); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- OR8G5 | c.-14-3C>A | Splice Region (SNP) | VAF 70/346 reads (20%) | called by muse, mutect2, varscan2
- OR8K5 | c.12_13del p.H4Qfs*7 | Frame Shift Del (DEL) | VAF 44/254 reads (17%) | called by pindel, varscan2
- ORC6 | c.730G>T p.A244S | Missense Mutation (SNP) | VAF 28/342 reads (8%) | SIFT tolerated (0.1); PolyPhen benign (0.062); called by muse, mutect2
- OTOG | c.5938C>A p.R1980S | Missense Mutation (SNP) | VAF 104/479 reads (22%) | SIFT tolerated (0.82); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- PASD1 | c.1192C>A p.Q398K | Missense Mutation (SNP) | VAF 47/511 reads (9%) | SIFT tolerated (0.11); PolyPhen benign (0.224); called by muse, mutect2
- PAX7 | c.199A>T p.I67F | Missense Mutation (SNP) | VAF 97/556 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PDE3A | c.2299C>G p.L767V | Missense Mutation (SNP) | VAF 90/490 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); called by muse, varscan2
- PDZK1 | c.838G>C p.A280P | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by mutect2, varscan2
- PEDS1-UBE2V1 | c.1004A>G p.Q335R | Missense Mutation (SNP) | VAF 38/355 reads (11%) | SIFT tolerated, low confidence (0.06); PolyPhen probably damaging (0.951); called by muse, mutect2, varscan2
- PGR | c.2611T>A p.Y871N | Missense Mutation (SNP) | VAF 83/438 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PIGM | c.91G>T p.A31S | Missense Mutation (SNP) | VAF 51/581 reads (9%) | SIFT tolerated (0.08); PolyPhen benign (0.127); called by muse, mutect2
- PKHD1L1 | c.6107C>T p.S2036L | Missense Mutation (SNP) | VAF 63/370 reads (17%) | SIFT tolerated (0.07); PolyPhen benign (0.033); called by muse, mutect2, varscan2
- PKNOX2 | c.1034G>T p.R345L | Missense Mutation (SNP) | VAF 80/367 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- PLD5 | c.231C>A p.C77* (on ENST00000442594; = p.C15* on NM_001195811.1 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 79/409 reads (19%) | called by muse, mutect2, varscan2
- PLEKHA6 | c.3128G>T p.S1043I | Missense Mutation (SNP) | VAF 86/419 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- PLEKHG3 | c.193T>A p.S65T | Missense Mutation (SNP) | VAF 146/528 reads (28%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.502); called by muse, mutect2, varscan2
- PLEKHG4B | c.98C>T p.P33L | Missense Mutation (SNP) | VAF 99/550 reads (18%) | SIFT tolerated (0.36); PolyPhen benign (0.051); called by muse, mutect2, varscan2
- PLK5 | c.821T>C p.V274A | Missense Mutation (SNP) | VAF 80/295 reads (27%) | SIFT tolerated (0.09); PolyPhen benign (0.011); called by muse, varscan2
- PLPPR4 | c.824C>G p.S275C | Missense Mutation (SNP) | VAF 26/339 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); called by muse, mutect2
- PLSCR4 | c.421A>G p.N141D | Missense Mutation (SNP) | VAF 41/196 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- PLXNA1 | c.3484G>T p.E1162* | Nonsense Mutation (SNP) | VAF 85/374 reads (23%) | called by muse, mutect2, varscan2
- PLXNA2 | c.5534A>G p.N1845S | Missense Mutation (SNP) | VAF 40/506 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.959); called by muse, mutect2
- PNPLA5 | c.227G>C p.G76A | Missense Mutation (SNP) | VAF 28/410 reads (7%) | SIFT deleterious (0); PolyPhen benign (0.01); called by muse, mutect2
- POGZ | c.181G>T p.V61F | Missense Mutation (SNP) | VAF 132/529 reads (25%) | SIFT tolerated, low confidence (0.46); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- POLRMT | c.259G>T p.D87Y | Missense Mutation (SNP) | VAF 174/589 reads (30%) | SIFT deleterious (0.01); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- POTEA | c.7G>A p.A3T | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.511); called by muse, mutect2, varscan2
- POTEE | c.2137G>T p.G713C | Missense Mutation (SNP) | VAF 68/405 reads (17%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- PPFIA2 | c.2056G>C p.A686P | Missense Mutation (SNP) | VAF 117/522 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- PPIL3 | c.146T>C p.F49S | Missense Mutation (SNP) | VAF 64/314 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP1R32 | c.23G>T p.G8V | Missense Mutation (SNP) | VAF 108/501 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- PPP4R3C | c.259C>T p.P87S | Missense Mutation (SNP) | VAF 66/366 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.055); called by muse, mutect2, varscan2
- PRAG1 | c.3487G>T p.G1163W | Missense Mutation (SNP) | VAF 77/306 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.864); called by mutect2, varscan2
- PRKCG | c.736G>A p.D246N | Missense Mutation (SNP) | VAF 67/797 reads (8%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.912); called by muse, mutect2
- PRKD2 | c.2511G>T p.W837C | Missense Mutation (SNP) | VAF 225/706 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- PRRT4 | c.2630A>T p.Q877L | Missense Mutation (SNP) | VAF 87/369 reads (24%) | SIFT deleterious (0); PolyPhen possibly damaging (0.564); called by muse, mutect2, varscan2
- PRRX2 | c.311A>T p.Q104L | Missense Mutation (SNP) | VAF 77/486 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); called by muse, mutect2, varscan2
- PXK | c.193A>T p.S65C | Missense Mutation (SNP) | VAF 31/247 reads (13%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.956); called by muse, mutect2, varscan2
- QPCT | c.488del p.P163Hfs*4 | Frame Shift Del (DEL) | VAF 55/465 reads (12%) | called by mutect2, pindel, varscan2
- RAB12 | c.507G>T p.Q169H | Missense Mutation (SNP) | VAF 86/372 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- RABGAP1 | c.1148G>A p.G383E | Missense Mutation (SNP) | VAF 29/328 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.938); called by muse, mutect2
- RALGAPA1 | c.106G>C p.E36Q | Missense Mutation (SNP) | VAF 76/595 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- RBBP8NL | c.947A>T p.D316V | Missense Mutation (SNP) | VAF 68/524 reads (13%) | SIFT tolerated (0.19); PolyPhen benign (0.073); called by muse, mutect2, varscan2
- RBMX2 | c.202G>T p.V68L | Missense Mutation (SNP) | VAF 29/424 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.216); called by muse, mutect2
- RGS20 | c.622T>C p.C208R (on ENST00000297313 / NM_170587.4; = p.C61R on NM_003702.4) | Missense Mutation (SNP) | VAF 145/701 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.595); called by muse, mutect2, varscan2
- RIMBP2 | c.1000G>C p.V334L | Missense Mutation (SNP) | VAF 138/617 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); called by muse, mutect2, varscan2
- RNPC3 | c.631G>T p.D211Y | Missense Mutation (SNP) | VAF 29/320 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.116); called by muse, mutect2
- RP1 | c.2788C>A p.L930I | Missense Mutation (SNP) | VAF 100/443 reads (23%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.869); called by muse, mutect2, varscan2
- RTL9 | c.2213C>A p.S738Y | Missense Mutation (SNP) | VAF 70/750 reads (9%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.66); called by muse, mutect2
- RTL9 | c.4084G>T p.E1362* | Nonsense Mutation (SNP) | VAF 50/631 reads (8%) | called by muse, mutect2
- RTTN | c.4987_4988insT p.A1663Vfs*10 | Frame Shift Ins (INS) | VAF 48/355 reads (14%) | called by mutect2, pindel*, varscan2
- RUNDC3B | c.1067A>T p.N356I | Missense Mutation (SNP) | VAF 80/495 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.655); called by muse, mutect2, varscan2
- S1PR1 | c.868C>A p.L290I | Missense Mutation (SNP) | VAF 80/470 reads (17%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- SAMD9 | c.2813G>T p.C938F | Missense Mutation (SNP) | VAF 83/396 reads (21%) | SIFT deleterious (0); PolyPhen possibly damaging (0.854); called by muse, mutect2, varscan2
- SCD5 | c.405C>A p.H135Q | Missense Mutation (SNP) | VAF 69/320 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SCYGR4 | c.26G>A p.C9Y | Missense Mutation (SNP) | VAF 47/459 reads (10%) | called by muse, mutect2, varscan2
- SEMA3D | c.1733G>A p.G578D | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- SEZ6L | c.1196C>T p.P399L | Missense Mutation (SNP) | VAF 69/374 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- SHROOM4 | c.4207G>T p.E1403* | Nonsense Mutation (SNP) | VAF 85/403 reads (21%) | called by muse, mutect2, varscan2
- SIGLEC10 | c.919G>T p.G307W | Missense Mutation (SNP) | VAF 89/573 reads (16%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.98); called by muse, mutect2, varscan2
- SLC17A1 | c.1176del p.R393Dfs*12 | Frame Shift Del (DEL) | VAF 48/261 reads (18%) | called by mutect2, pindel, varscan2
- SLC17A5 | c.789G>C p.K263N | Missense Mutation (SNP) | VAF 45/294 reads (15%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); called by muse, mutect2, varscan2
- SLC1A4 | c.295G>T p.V99L | Missense Mutation (SNP) | VAF 71/585 reads (12%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.718); called by muse, mutect2, varscan2
- SLC22A7 | c.658G>T p.E220* (on ENST00000372585 / NM_153320.2; = p.E218* on NM_006672.3) | Nonsense Mutation (SNP) | VAF 48/329 reads (15%) | called by muse, mutect2, varscan2
- SLC4A11 | c.1315G>A p.A439T | Missense Mutation (SNP) | VAF 54/308 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- SLC9A9 | c.1732G>A p.V578M | Missense Mutation (SNP) | VAF 50/259 reads (19%) | SIFT tolerated (0.06); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- SLCO5A1 | c.1993G>T p.A665S | Missense Mutation (SNP) | VAF 34/381 reads (9%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.851); called by muse, mutect2
- SMARCD2 | c.153_154insT p.G52Wfs*92 | Frame Shift Ins (INS) | VAF 98/602 reads (16%) | called by pindel, varscan2
- SMCHD1 | c.1578G>T p.L526F | Missense Mutation (SNP) | VAF 65/439 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMOC1 | c.1188G>T p.K396N | Missense Mutation (SNP) | VAF 98/404 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- SMOC2 | c.1289C>T p.P430L (on ENST00000356284 / NM_001166412.2; = p.P441L on NM_022138.3) | Missense Mutation (SNP) | VAF 32/293 reads (11%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.351); called by muse, mutect2, varscan2
- SNURF | c.106C>A p.Q36K | Missense Mutation (SNP) | VAF 26/366 reads (7%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.014); called by muse, mutect2
- SPRYD4 | c.205G>T p.E69* | Nonsense Mutation (SNP) | VAF 77/548 reads (14%) | called by muse, mutect2, varscan2
- ST6GAL2 | c.776C>A p.A259E | Missense Mutation (SNP) | VAF 147/780 reads (19%) | PolyPhen benign (0.334); called by muse, mutect2, varscan2
- STRN4 | c.1463G>T p.R488L | Missense Mutation (SNP) | VAF 86/348 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- STYXL2 | c.2117C>T p.P706L | Missense Mutation (SNP) | VAF 168/632 reads (27%) | SIFT deleterious (0.03); PolyPhen benign (0.035); called by muse, mutect2, varscan2
- SV2C | c.178C>T p.P60S | Missense Mutation (SNP) | VAF 24/348 reads (7%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); called by muse, mutect2
- SVEP1 | c.2303A>T p.Y768F | Missense Mutation (SNP) | VAF 47/419 reads (11%) | SIFT tolerated (0.74); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- SZT2 | c.1742G>T p.R581L | Missense Mutation (SNP) | VAF 49/411 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TAF4B | c.97G>A p.V33M | Missense Mutation (SNP) | VAF 154/631 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.372); called by muse, mutect2, varscan2
- TAGAP | c.847G>T p.V283L | Missense Mutation (SNP) | VAF 19/335 reads (6%) | SIFT tolerated (0.78); PolyPhen benign (0); called by muse, mutect2
- TBCK | c.1418G>A p.G473D (on ENST00000273980 / NM_001163436.4; = p.G410D on NM_033115.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 30/352 reads (9%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.68); called by muse, mutect2
- TBX20 | c.380G>T p.R127M | Missense Mutation (SNP) | VAF 55/274 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- TBX4 | c.1162C>A p.P388T | Missense Mutation (SNP) | VAF 76/670 reads (11%) | SIFT tolerated (0.36); PolyPhen benign (0.066); called by muse, mutect2, varscan2
- TDRD6 | c.536T>A p.L179Q | Missense Mutation (SNP) | VAF 60/548 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- TEAD4 | c.732G>T p.K244N | Missense Mutation (SNP) | VAF 41/336 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.101); called by muse, mutect2, varscan2
- TENM1 | c.5321G>C p.R1774T | Missense Mutation (SNP) | VAF 63/815 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.358); called by muse, mutect2
- TEX11 | c.440C>A p.A147D (on ENST00000344304; = p.A132D on NM_031276.3) | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.521); called by muse, mutect2
- TEX15 | c.2652T>G p.N884K (on ENST00000256246; = p.N1267K on NM_001350162.2) | Missense Mutation (SNP) | VAF 46/290 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.053); called by muse, mutect2, varscan2
- TEX36 | c.17G>C p.R6P | Missense Mutation (SNP) | VAF 101/518 reads (19%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.68); called by muse, mutect2, varscan2
- THBS2 | c.1295C>A p.T432N | Missense Mutation (SNP) | VAF 46/324 reads (14%) | SIFT tolerated, low confidence (0.45); PolyPhen benign (0); called by muse, mutect2, varscan2
- THSD7A | c.391C>A p.Q131K | Missense Mutation (SNP) | VAF 83/429 reads (19%) | SIFT tolerated (0.74); PolyPhen benign (0.017); called by muse, mutect2, varscan2
- TIAM1 | c.4236G>T p.Q1412H | Missense Mutation (SNP) | VAF 52/506 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.887); called by muse, mutect2
- TINAG | c.370G>T p.G124C | Missense Mutation (SNP) | VAF 57/335 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.554); called by muse, mutect2, varscan2
- TJP1 | c.5026T>G p.C1676G | Missense Mutation (SNP) | VAF 100/533 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMEM132C | c.134T>A p.L45Q | Missense Mutation (SNP) | VAF 71/444 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); called by muse, mutect2, varscan2
- TMEM185A | c.733C>A p.P245T | Missense Mutation (SNP) | VAF 38/667 reads (6%) | SIFT tolerated (0.66); PolyPhen benign (0.009); called by muse, mutect2
- TMEM271 | c.1033G>T p.G345W | Missense Mutation (SNP) | VAF 120/665 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- TMPRSS15 | c.1321A>T p.I441F | Missense Mutation (SNP) | VAF 34/301 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.782); called by muse, mutect2, varscan2
- TNN | c.1513G>A p.E505K | Missense Mutation (SNP) | VAF 124/469 reads (26%) | SIFT tolerated (0.72); PolyPhen benign (0.388); called by muse, mutect2, varscan2
- TOX2 | c.449T>A p.M150K (on ENST00000358131 / NM_001098798.2; = p.M99K on NM_032883.3) | Missense Mutation (SNP) | VAF 53/456 reads (12%) | SIFT deleterious (0); PolyPhen benign (0.388); called by muse, mutect2
- TRANK1 | c.2233G>A p.G745R | Missense Mutation (SNP) | VAF 168/570 reads (29%) | SIFT tolerated (0.1); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- TRAPPC3L | c.158C>A p.T53K | Missense Mutation (SNP) | VAF 42/475 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.412); called by muse, mutect2
- TRGV5 | c.239G>T p.G80V | Missense Mutation (SNP) | VAF 56/372 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, varscan2
- TRIM37 | c.1691A>T p.Y564F | Missense Mutation (SNP) | VAF 24/234 reads (10%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- TRIM4 | c.1171G>T p.E391* | Nonsense Mutation (SNP) | VAF 98/498 reads (20%) | called by muse, mutect2, varscan2
- TRIM42 | c.1414A>G p.I472V | Missense Mutation (SNP) | VAF 111/403 reads (28%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- TRPM2 | c.1711G>C p.D571H | Missense Mutation (SNP) | VAF 77/612 reads (13%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.619); called by muse, mutect2, varscan2
- TSPYL2 | c.457_458insA p.G153Efs*9 | Frame Shift Ins (INS) | VAF 132/795 reads (17%) | called by mutect2, pindel, varscan2
- TTC28 | c.5428C>A p.P1810T | Missense Mutation (SNP) | VAF 55/807 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.92); called by muse, mutect2
- TWIST1 | c.119G>A p.R40H | Missense Mutation (SNP) | VAF 73/389 reads (19%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.454); called by muse, mutect2, varscan2
- TXLNB | c.251G>T p.R84M | Missense Mutation (SNP) | VAF 67/470 reads (14%) | SIFT tolerated (0.07); PolyPhen benign (0); called by muse, mutect2, varscan2
- UBE2J2 | c.653G>T p.G218V | Missense Mutation (SNP) | VAF 102/789 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.403); called by muse, mutect2, varscan2
- UBXN10 | c.226A>G p.S76G | Missense Mutation (SNP) | VAF 65/519 reads (13%) | SIFT tolerated (0.18); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- UGT1A9 | c.761G>T p.R254L | Missense Mutation (SNP) | VAF 68/478 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by mutect2, varscan2
- UNC5C | c.1676T>C p.I559T | Missense Mutation (SNP) | VAF 62/279 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.113); called by muse, mutect2, varscan2
- UPRT | c.115G>T p.A39S | Missense Mutation (SNP) | VAF 75/862 reads (9%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.223); called by muse, mutect2
- UROC1 | c.1630G>T p.D544Y | Missense Mutation (SNP) | VAF 62/316 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- UTF1 | c.706G>T p.D236Y | Missense Mutation (SNP) | VAF 89/475 reads (19%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.136); called by muse, mutect2, varscan2
- VAMP7 | c.392C>A p.A131D | Missense Mutation (SNP) | VAF 43/418 reads (10%) | SIFT tolerated (0.14); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- WDCP | c.1778C>G p.P593R | Missense Mutation (SNP) | VAF 39/444 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- WDR81 | c.3998G>T p.R1333L (on ENST00000409644 / NM_001163809.2; = p.R282L on NM_152348.4) | Missense Mutation (SNP) | VAF 145/524 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.935); called by muse, mutect2, varscan2
- XIRP2 | c.937G>C p.V313L (on ENST00000628543; = p.V488L on NM_152381.6) | Missense Mutation (SNP) | VAF 41/365 reads (11%) | SIFT tolerated (1); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- YWHAG | c.408_433del p.E136Dfs*34 | Frame Shift Del (DEL) | VAF 108/702 reads (15%) | called by mutect2, pindel
- ZBTB8A | c.1259T>C p.L420P | Missense Mutation (SNP) | VAF 47/324 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2, varscan2
- ZEB1 | c.1127C>A p.T376N | Missense Mutation (SNP) | VAF 94/496 reads (19%) | SIFT tolerated (0.57); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZNF185 | c.2062C>A p.L688I | Missense Mutation (SNP) | VAF 38/309 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); called by mutect2, varscan2
- ZNF189 | c.1466G>T p.C489F | Missense Mutation (SNP) | VAF 51/475 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ZNF225 | c.1930A>G p.R644G | Missense Mutation (SNP) | VAF 36/303 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.891); called by muse, mutect2, varscan2
- ZNF260 | c.282G>T p.Q94H | Missense Mutation (SNP) | VAF 101/464 reads (22%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.805); called by muse, mutect2, varscan2
- ZNF329 | c.435G>C p.K145N | Missense Mutation (SNP) | VAF 104/398 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.444); called by muse, mutect2, varscan2
- ZNF469 | c.4412C>A p.P1471H (on ENST00000437464; = p.P1499H on NM_001367624.2) | Missense Mutation (SNP) | VAF 106/550 reads (19%) | SIFT deleterious (0); PolyPhen possibly damaging (0.511); called by mutect2, varscan2
- ZNF746 | c.1316G>T p.G439V | Missense Mutation (SNP) | VAF 135/476 reads (28%) | SIFT tolerated (0.11); PolyPhen benign (0.241); called by muse, mutect2, varscan2
- ZP4 | c.73G>T p.A25S | Missense Mutation (SNP) | VAF 90/418 reads (22%) | SIFT tolerated (0.72); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- ZXDB | c.2033C>A p.S678Y | Missense Mutation (SNP) | VAF 33/624 reads (5%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.991); called by muse, mutect2
- ABCA13 | c.6534A>T p.A2178= | Silent (SNP) | VAF 61/331 reads (18%) | called by muse, mutect2, varscan2
- ABCA2 | c.396C>T p.R132= (on ENST00000614293; = p.R102= on NM_001606.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 68/463 reads (15%) | catalogued as rs373842222; called by muse, mutect2, varscan2
- ADAMTS15 | c.2229G>T p.V743= | Silent (SNP) | VAF 53/500 reads (11%) | called by muse, mutect2, varscan2
- ADAMTS5 | c.1482C>A p.T494= | Silent (SNP) | VAF 45/405 reads (11%) | called by mutect2, varscan2
- ADGB | c.4461C>T p.S1487= | Silent (SNP) | VAF 49/472 reads (10%) | called by muse, mutect2, varscan2
- ADGRB3 | c.2271A>G p.S757= | Silent (SNP) | VAF 29/302 reads (10%) | called by muse, mutect2
- ADGRG4 | c.1920C>T p.S640= | Silent (SNP) | VAF 62/640 reads (10%) | called by muse, mutect2
- AICDA | c.330C>T p.T110= | Silent (SNP) | VAF 102/564 reads (18%) | catalogued as rs1221122918, COSV104392632; called by muse, mutect2, varscan2
- ANKRD54 | c.171G>C p.A57= | Silent (SNP) | VAF 141/594 reads (24%) | called by muse, mutect2, varscan2
- APCDD1 | c.1212G>T p.V404= | Silent (SNP) | VAF 135/762 reads (18%) | catalogued as COSV62372572; called by muse, mutect2, varscan2
- APLNR | c.330C>T p.F110= | Silent (SNP) | VAF 51/461 reads (11%) | catalogued as rs769911270, COSV57241982; called by muse, mutect2, varscan2
- APOBR | c.930T>A p.A310= | Silent (SNP) | VAF 140/615 reads (23%) | called by muse, mutect2, varscan2
- ARAP1 | c.3087G>T p.S1029= (on ENST00000393609 / NM_001040118.2; = p.S784= on NM_015242.4) | Silent (SNP) | VAF 140/588 reads (24%) | catalogued as rs1239812666; called by muse, mutect2, varscan2
- ARFGAP1 | c.159G>T p.G53= | Silent (SNP) | VAF 32/295 reads (11%) | called by muse, mutect2, varscan2
- ARSD | c.327C>T p.A109= | Silent (SNP) | VAF 72/490 reads (15%) | called by muse, mutect2, varscan2
- ASAP2 | c.213T>C p.N71= | Silent (SNP) | VAF 61/314 reads (19%) | catalogued as rs1217328936; called by muse, mutect2, varscan2
- ATAD5 | c.1575A>G p.T525= | Silent (SNP) | VAF 42/183 reads (23%) | catalogued as rs764289121; called by muse, mutect2, varscan2
- BACH2 | c.1209C>G p.S403= | Silent (SNP) | VAF 89/550 reads (16%) | called by muse, mutect2, varscan2
- BCL9 | c.1278G>T p.V426= | Silent (SNP) | VAF 210/684 reads (31%) | called by muse, mutect2, varscan2
- BCORL1 | c.78C>T p.N26= | Silent (SNP) | VAF 35/460 reads (8%) | called by muse, mutect2
- BMP15 | c.798C>A p.T266= | Silent (SNP) | VAF 56/360 reads (16%) | called by muse, varscan2
- BPGM | c.462G>T p.R154= | Silent (SNP) | VAF 88/395 reads (22%) | called by muse, mutect2, varscan2
- BPIFA3 | c.222A>T p.P74= | Silent (SNP) | VAF 44/493 reads (9%) | called by muse, mutect2
- BTNL2 | c.978G>C p.L326= | Silent (SNP) | VAF 44/475 reads (9%) | called by muse, mutect2
- C1orf112 | c.585C>T p.S195= | Silent (SNP) | VAF 34/318 reads (11%) | catalogued as rs984066312; called by muse, mutect2, varscan2
- CALN1 | c.642C>G p.L214= (on ENST00000329008 / NM_001017440.3; = p.L256= on NM_031468.4) | Silent (SNP) | VAF 49/304 reads (16%) | catalogued as COSV100209539; called by muse, mutect2, varscan2
- CARD11 | c.2757C>T p.V919= | Silent (SNP) | VAF 95/660 reads (14%) | catalogued as COSV62757109; called by muse, mutect2, varscan2
- CCER1 | c.168C>G p.P56= | Silent (SNP) | VAF 117/667 reads (18%) | catalogued as COSV62646951; called by muse, mutect2, varscan2
- CCL2 | c.180C>A p.P60= | Silent (SNP) | VAF 38/370 reads (10%) | catalogued as COSV56774169; called by muse, mutect2
- CDCA3 | c.243C>T p.S81= | Silent (SNP) | VAF 53/276 reads (19%) | called by muse, varscan2
- CDH7 | c.516G>T p.V172= | Silent (SNP) | VAF 60/336 reads (18%) | catalogued as COSV100541755; called by muse, mutect2, varscan2
- CDH8 | c.10C>A p.R4= | Silent (SNP) | VAF 55/485 reads (11%) | catalogued as rs139797882, COSV54872322; ClinVar: likely benign; called by muse, mutect2, varscan2
- CDK2AP2 | c.177G>T p.V59= | Silent (SNP) | VAF 69/321 reads (21%) | catalogued as COSV100039363; called by muse, mutect2, varscan2
- CFAP45 | c.264A>C p.R88= | Silent (SNP) | VAF 75/308 reads (24%) | called by muse, mutect2, varscan2
- CHD6 | c.5451A>T p.P1817= | Silent (SNP) | VAF 72/418 reads (17%) | called by muse, mutect2, varscan2
- CHD6 | c.3417G>T p.V1139= | Silent (SNP) | VAF 68/513 reads (13%) | called by muse, mutect2, varscan2
- CMYA5 | c.384G>T p.V128= | Silent (SNP) | VAF 93/359 reads (26%) | called by muse, mutect2, varscan2
- CNGA2 | c.1396C>T p.L466= | Silent (SNP) | VAF 101/452 reads (22%) | catalogued as COSV61706246; called by muse, mutect2, varscan2
- CNTNAP5 | c.1482C>A p.P494= | Silent (SNP) | VAF 56/321 reads (17%) | catalogued as COSV70490746; called by muse, mutect2, varscan2
- CSH1 | c.123C>A p.L41= | Silent (SNP) | VAF 66/301 reads (22%) | called by muse, mutect2, varscan2
- CST4 | c.141C>A p.A47= | Silent (SNP) | VAF 43/320 reads (13%) | catalogued as COSV99463251; called by muse, mutect2, varscan2
- CST9L | c.348G>T p.L116= | Silent (SNP) | VAF 44/215 reads (20%) | catalogued as COSV65408380; called by muse, mutect2, varscan2
- CTNND2 | c.1449G>T p.A483= | Silent (SNP) | VAF 136/641 reads (21%) | called by muse, mutect2, varscan2
- CWC22 | c.285G>T p.G95= | Silent (SNP) | VAF 94/529 reads (18%) | called by muse, mutect2, varscan2
- CWC25 | c.1077A>G p.R359= | Silent (SNP) | VAF 55/610 reads (9%) | called by muse, mutect2
- DDX19A | c.351A>T p.I117= | Silent (SNP) | VAF 44/425 reads (10%) | called by muse, mutect2
- DNAI3 | c.645C>A p.A215= | Silent (SNP) | VAF 65/366 reads (18%) | catalogued as rs931646748; called by muse, mutect2, varscan2
- DPY19L2 | c.825T>C p.L275= | Silent (SNP) | VAF 31/195 reads (16%) | called by muse, mutect2, varscan2
- EDARADD | c.573G>T p.V191= (on ENST00000334232 / NM_145861.4; = p.V181= on NM_080738.4) | Silent (SNP) | VAF 57/612 reads (9%) | called by muse, mutect2
- EDEM2 | c.933C>G p.V311= | Silent (SNP) | VAF 47/350 reads (13%) | called by muse, mutect2, varscan2
- EFCAB8 | c.600G>T p.P200= | Silent (SNP) | VAF 55/404 reads (14%) | catalogued as COSV68700014; called by muse, mutect2, varscan2
- ELFN1 | c.2184G>A p.E728= | Silent (SNP) | VAF 84/968 reads (9%) | called by muse, mutect2
- ELK1 | c.85C>A p.R29= | Silent (SNP) | VAF 112/734 reads (15%) | called by muse, mutect2, varscan2
- ENOX1 | c.168C>A p.G56= | Silent (SNP) | VAF 35/311 reads (11%) | called by muse, mutect2, varscan2
- EPB41L4B | c.2253C>A p.T751= | Silent (SNP) | VAF 67/381 reads (18%) | called by muse, mutect2, varscan2
- EPHB6 | c.1389T>A p.A463= | Silent (SNP) | VAF 154/612 reads (25%) | called by muse, mutect2, varscan2
- ESR1 | c.264G>T p.A88= | Silent (SNP) | VAF 82/652 reads (13%) | called by mutect2, varscan2
- FAM53C | c.327C>T p.P109= | Silent (SNP) | VAF 192/555 reads (35%) | called by muse, mutect2, varscan2
- FAM71C | c.624C>A p.A208= | Silent (SNP) | VAF 47/297 reads (16%) | called by muse, mutect2, varscan2
- FCGR3A | c.117G>A p.E39= | Silent (SNP) | VAF 54/1070 reads (5%) | called by muse, mutect2
- FCN1 | c.519C>A p.A173= | Silent (SNP) | VAF 46/355 reads (13%) | catalogued as rs763319101; called by muse, mutect2, varscan2
- FOXL2NB | c.258G>T p.A86= | Silent (SNP) | VAF 129/486 reads (27%) | catalogued as COSV100374808; called by muse, mutect2, varscan2
- FOXN4 | c.1197C>A p.A399= | Silent (SNP) | VAF 157/702 reads (22%) | called by muse, mutect2, varscan2
- FOXO4 | c.1281G>C p.L427= | Silent (SNP) | VAF 104/769 reads (14%) | called by muse, mutect2, varscan2
- FSIP2 | c.8811C>A p.P2937= | Silent (SNP) | VAF 74/373 reads (20%) | called by muse, mutect2, varscan2
- FTHL17 | c.130C>A p.R44= | Silent (SNP) | VAF 121/705 reads (17%) | catalogued as COSV63266854; called by muse, mutect2, varscan2
- FUT1 | c.729G>T p.R243= | Silent (SNP) | VAF 51/685 reads (7%) | called by muse, mutect2
- GAL3ST3 | c.816C>A p.A272= | Silent (SNP) | VAF 55/345 reads (16%) | called by muse, mutect2, varscan2
- GATAD2B | c.750A>T p.S250= | Silent (SNP) | VAF 50/577 reads (9%) | called by muse, mutect2
- GJB3 | c.135G>C p.G45= | Silent (SNP) | VAF 153/627 reads (24%) | called by muse, mutect2, varscan2
- H1-2 | c.387G>A p.K129= | Silent (SNP) | VAF 94/375 reads (25%) | catalogued as rs766767455, COSV59190607; called by muse, mutect2, varscan2
- HOXA2 | c.1044C>G p.L348= | Silent (SNP) | VAF 110/440 reads (25%) | catalogued as COSV56065913; called by muse, mutect2, varscan2
- HOXB3 | c.282C>A p.A94= | Silent (SNP) | VAF 86/780 reads (11%) | called by muse, mutect2, varscan2
- IDH3G | c.840C>A p.V280= | Silent (SNP) | VAF 84/777 reads (11%) | called by muse, mutect2, varscan2
- IGKV1-8 | c.300T>A p.S100= | Silent (SNP) | VAF 84/303 reads (28%) | called by muse, mutect2, varscan2
- IL5RA | c.267C>A p.I89= | Silent (SNP) | VAF 101/328 reads (31%) | catalogued as COSV99842646; called by muse, mutect2, varscan2
- IQSEC2 | c.3486G>T p.L1162= | Silent (SNP) | VAF 102/600 reads (17%) | called by muse, varscan2
- ITGAE | c.2409C>A p.P803= | Silent (SNP) | VAF 131/445 reads (29%) | called by muse, mutect2, varscan2
- ITGAL | c.1191A>G p.P397= | Silent (SNP) | VAF 60/281 reads (21%) | called by muse, mutect2, varscan2
- ITIH5 | c.1926C>A p.A642= | Silent (SNP) | VAF 78/548 reads (14%) | called by muse, mutect2, varscan2
- JPH2 | c.531G>T p.P177= | Silent (SNP) | VAF 74/682 reads (11%) | called by muse, mutect2, varscan2
- KCNA6 | c.531C>G p.A177= | Silent (SNP) | VAF 83/501 reads (17%) | called by muse, mutect2, varscan2
- KCTD21 | c.216G>A p.E72= | Silent (SNP) | VAF 57/538 reads (11%) | called by muse, mutect2, varscan2
- KIAA1210 | c.1701C>A p.G567= | Silent (SNP) | VAF 66/840 reads (8%) | catalogued as COSV68175445; called by muse, mutect2
- KIAA1549L | c.2805T>G p.P935= (on ENST00000321505; = p.P1232= on NM_012194.3) | Silent (SNP) | VAF 68/275 reads (25%) | called by muse, mutect2, varscan2
- KIAA2026 | c.4362A>G p.S1454= | Silent (SNP) | VAF 72/350 reads (21%) | called by muse, mutect2, varscan2
- KIR2DS4 | c.258C>A p.S86= | Silent (SNP) | VAF 130/502 reads (26%) | called by muse, mutect2, varscan2
- KIR3DL2 | c.288G>A p.R96= | Silent (SNP) | VAF 24/220 reads (11%) | called by muse, mutect2, varscan2
- KIR3DL3 | c.1083A>T p.A361= | Silent (SNP) | VAF 106/418 reads (25%) | called by muse, mutect2, varscan2
- KRT31 | c.393C>T p.I131= | Silent (SNP) | VAF 89/403 reads (22%) | catalogued as rs553792126, COSV52433404; called by muse, mutect2, varscan2
- KRTAP13-4 | c.327C>A p.S109= | Silent (SNP) | VAF 30/390 reads (8%) | called by muse, mutect2
- KRTAP9-4 | c.312C>T p.T104= | Silent (SNP) | VAF 106/906 reads (12%) | called by muse, mutect2, varscan2
- L3MBTL1 | c.600G>T p.A200= (on ENST00000418998 / NM_001377303.1; = p.A110= on NM_015478.7) | Silent (SNP) | VAF 64/530 reads (12%) | catalogued as COSV100917327, COSV64232199; called by muse, mutect2, varscan2
- LAIR2 | c.81C>A p.P27= | Silent (SNP) | VAF 62/522 reads (12%) | called by muse, varscan2
- LAMB3 | c.3294G>C p.L1098= | Silent (SNP) | VAF 159/609 reads (26%) | called by muse, mutect2, varscan2
- LCP2 | c.786A>G p.P262= | Silent (SNP) | VAF 109/366 reads (30%) | called by muse, mutect2, varscan2
- LEPR | c.1797A>G p.P599= | Silent (SNP) | VAF 77/379 reads (20%) | called by muse, mutect2, varscan2
- LILRA4 | c.975C>G p.S325= | Silent (SNP) | VAF 128/537 reads (24%) | catalogued as COSV99392800; called by muse, mutect2, varscan2
- LOXL3 | c.840C>T p.S280= | Silent (SNP) | VAF 149/707 reads (21%) | called by muse, mutect2, varscan2
- MAGEA8 | c.327G>T p.R109= | Silent (SNP) | VAF 66/640 reads (10%) | called by muse, mutect2, varscan2
- MAGEH1 | c.501A>G p.A167= | Silent (SNP) | VAF 56/985 reads (6%) | called by muse, mutect2
- MAGEL2 | c.114G>T p.R38= | Silent (SNP) | VAF 119/587 reads (20%) | called by muse, mutect2, varscan2
- MAGI2 | c.3285G>T p.P1095= | Silent (SNP) | VAF 146/664 reads (22%) | catalogued as COSV62704708; called by muse, mutect2, varscan2
- MBL2 | c.165C>G p.T55= | Silent (SNP) | VAF 67/344 reads (19%) | catalogued as COSV100906366; called by muse, mutect2, varscan2
- MC2R | c.306C>A p.A102= | Silent (SNP) | VAF 91/516 reads (18%) | called by muse, mutect2, varscan2
- MEGF11 | c.1215G>A p.L405= | Silent (SNP) | VAF 95/652 reads (15%) | called by muse, mutect2, varscan2
- MEGF8 | c.5550G>T p.G1850= (on ENST00000251268 / NM_001271938.2; = p.G1783= on NM_001410.3) | Silent (SNP) | VAF 66/654 reads (10%) | catalogued as COSV52100799; called by muse, mutect2, varscan2
- METTL23 | c.189G>A p.R63= | Silent (SNP) | VAF 48/568 reads (8%) | called by muse, mutect2
- MFSD2B | c.103A>C p.R35= | Silent (SNP) | VAF 41/333 reads (12%) | called by muse, mutect2, varscan2
- MROH2A | c.1635C>T p.S545= | Silent (SNP) | VAF 71/483 reads (15%) | catalogued as rs1246711405; called by muse, mutect2, varscan2
- MROH2A | c.3063G>T p.L1021= | Silent (SNP) | VAF 66/353 reads (19%) | called by muse, mutect2, varscan2
- MRPS35 | c.825T>C p.N275= | Silent (SNP) | VAF 71/389 reads (18%) | called by muse, mutect2, varscan2
- MYF6 | c.480G>T p.L160= | Silent (SNP) | VAF 75/347 reads (22%) | called by muse, varscan2
- MYLK2 | c.1431C>T p.S477= | Silent (SNP) | VAF 18/246 reads (7%) | catalogued as rs764056444; ClinVar: likely benign / uncertain significance; called by muse, mutect2
- MYO18B | c.5889C>A p.A1963= | Silent (SNP) | VAF 49/462 reads (11%) | called by muse, mutect2, varscan2
- MYT1L | c.1314C>T p.I438= | Silent (SNP) | VAF 54/630 reads (9%) | catalogued as rs1372627035, COSV67715216; called by muse, mutect2
- NAV3 | c.1476A>G p.T492= | Silent (SNP) | VAF 83/494 reads (17%) | catalogued as rs768411330; called by muse, mutect2, varscan2
- NEFL | c.780C>T p.D260= | Silent (SNP) | VAF 106/609 reads (17%) | catalogued as rs878854817; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLGN4X | c.786G>T p.L262= | Silent (SNP) | VAF 84/481 reads (17%) | called by muse, mutect2, varscan2
- NME5 | c.24T>G p.P8= | Silent (SNP) | VAF 25/261 reads (10%) | called by muse, mutect2, varscan2
- NRIP1 | c.2910C>T p.T970= | Silent (SNP) | VAF 42/380 reads (11%) | called by muse, mutect2, varscan2
- OCA2 | c.441G>C p.L147= | Silent (SNP) | VAF 81/765 reads (11%) | called by muse, mutect2, varscan2
- OR10G4 | c.321G>T p.G107= | Silent (SNP) | VAF 50/700 reads (7%) | catalogued as COSV57978507; called by muse, mutect2
- OR10G7 | c.477C>A p.T159= | Silent (SNP) | VAF 78/454 reads (17%) | catalogued as COSV100389789; called by muse, varscan2
- OR10W1 | c.246C>G p.T82= | Silent (SNP) | VAF 63/510 reads (12%) | called by muse, mutect2, varscan2
- OR14C36 | c.21G>A p.V7= | Silent (SNP) | VAF 111/389 reads (29%) | called by muse, mutect2, varscan2
- OR1A2 | c.474C>A p.P158= | Silent (SNP) | VAF 81/317 reads (26%) | catalogued as COSV67936087; called by muse, mutect2, varscan2
- OR2T3 | c.90C>T p.A30= | Silent (SNP) | VAF 126/758 reads (17%) | catalogued as COSV100613138; called by muse, mutect2
- OR5AP2 | c.405C>A p.P135= | Silent (SNP) | VAF 29/341 reads (9%) | catalogued as COSV100266444; called by muse, mutect2
- OR5AS1 | c.684C>T p.I228= | Silent (SNP) | VAF 44/510 reads (9%) | catalogued as rs1312393517, COSV100546325; called by muse, mutect2
- OR8K5 | c.654C>T p.Y218= | Silent (SNP) | VAF 34/435 reads (8%) | catalogued as COSV100537298; called by muse, mutect2
- P2RY8 | c.189C>A p.I63= | Silent (SNP) | VAF 154/840 reads (18%) | catalogued as rs780449772; called by muse, mutect2, varscan2
- PCDHB8 | c.1716C>A p.P572= | Silent (SNP) | VAF 233/804 reads (29%) | called by muse, mutect2, varscan2
- PCSK1N | c.483C>A p.A161= | Silent (SNP) | VAF 143/774 reads (18%) | called by muse, mutect2, varscan2
- PDCD1 | c.141G>T p.G47= | Silent (SNP) | VAF 133/799 reads (17%) | called by muse, mutect2, varscan2
- PIGO | c.357G>A p.R119= | Silent (SNP) | VAF 78/394 reads (20%) | catalogued as COSV53052906; called by muse, mutect2, varscan2
- PIK3C2G | c.1734C>T p.V578= | Silent (SNP) | VAF 34/214 reads (16%) | called by muse, mutect2, varscan2
- PLEKHD1 | c.579G>A p.V193= | Silent (SNP) | VAF 45/246 reads (18%) | called by muse, mutect2, varscan2
- PLXDC2 | c.222G>T p.A74= | Silent (SNP) | VAF 116/566 reads (20%) | catalogued as COSV65915709; called by muse, mutect2, varscan2
- PNPLA1 | c.1005T>A p.L335= (on ENST00000394571 / NM_001374623.1; = p.L240= on NM_173676.2) | Silent (SNP) | VAF 122/503 reads (24%) | called by muse, mutect2, varscan2
- POMC | c.7A>C p.R3= | Silent (SNP) | VAF 22/314 reads (7%) | called by muse, mutect2
- POPDC2 | c.132C>A p.G44= | Silent (SNP) | VAF 101/464 reads (22%) | called by muse, mutect2, varscan2
- POU3F4 | c.966G>T p.V322= | Silent (SNP) | VAF 48/584 reads (8%) | called by muse, mutect2
- PPP2R2B | c.978C>A p.R326= (on ENST00000394409; = p.R392= on NM_181674.2) | Silent (SNP) | VAF 81/307 reads (26%) | called by muse, mutect2, varscan2
- PROP1 | c.294C>A p.A98= | Silent (SNP) | VAF 193/664 reads (29%) | called by muse, mutect2, varscan2
- PRR16 | c.525C>G p.P175= (on ENST00000407149 / NM_001300783.2; = p.P152= on NM_016644.2) | Silent (SNP) | VAF 87/369 reads (24%) | catalogued as rs1278097781, COSV101088305; called by muse, mutect2, varscan2
- PRR32 | c.100C>T p.L34= | Silent (SNP) | VAF 43/776 reads (6%) | called by muse, mutect2
- PRUNE2 | c.2229G>T p.L743= | Silent (SNP) | VAF 42/387 reads (11%) | called by mutect2, varscan2
- PSG9 | c.477G>A p.R159= | Silent (SNP) | VAF 74/294 reads (25%) | catalogued as COSV99392042; called by muse, mutect2, varscan2
- PTH2R | c.762C>A p.I254= | Silent (SNP) | VAF 81/515 reads (16%) | catalogued as COSV55917088; called by muse, mutect2, varscan2
- PTPRF | c.453A>T p.T151= | Silent (SNP) | VAF 118/434 reads (27%) | called by muse, varscan2
- PVRIG | c.583C>A p.R195= | Silent (SNP) | VAF 64/367 reads (17%) | catalogued as rs138822111; called by muse, mutect2, varscan2
- RASSF9 | c.1083C>G p.A361= | Silent (SNP) | VAF 70/429 reads (16%) | called by muse, mutect2, varscan2
- RBM20 | c.2442C>T p.A814= | Silent (SNP) | VAF 43/660 reads (7%) | called by muse, mutect2
- RBM5 | c.1518G>T p.V506= | Silent (SNP) | VAF 37/300 reads (12%) | called by muse, mutect2, varscan2
- RCSD1 | c.130C>A p.R44= | Silent (SNP) | VAF 28/398 reads (7%) | catalogued as COSV63260072; called by muse, mutect2
- RFPL4B | c.414T>A p.T138= | Silent (SNP) | VAF 86/476 reads (18%) | called by muse, mutect2, varscan2
- RFWD3 | c.741A>T p.S247= | Silent (SNP) | VAF 45/250 reads (18%) | called by muse, varscan2
- RNF17 | c.1884G>T p.P628= | Silent (SNP) | VAF 36/448 reads (8%) | catalogued as rs922809271, COSV55038529; called by muse, mutect2
- RUVBL2 | c.474G>T p.V158= | Silent (SNP) | VAF 56/259 reads (22%) | called by muse, mutect2, varscan2
- RYR1 | c.5919G>A p.Q1973= | Silent (SNP) | VAF 174/571 reads (30%) | catalogued as rs1325551524; called by muse, mutect2, varscan2
- SCART1 | c.2892C>A p.I964= | Silent (SNP) | VAF 77/515 reads (15%) | called by muse, mutect2, varscan2
- SEL1L3 | c.2529C>G p.L843= | Silent (SNP) | VAF 82/389 reads (21%) | called by muse, mutect2, varscan2
- SGSM1 | c.3063G>T p.T1021= (on ENST00000400359 / NM_001039948.4; = p.T960= on NM_133454.3) | Silent (SNP) | VAF 62/323 reads (19%) | catalogued as COSV101240787; called by muse, mutect2, varscan2
- SLC2A4 | c.228C>T p.T76= | Silent (SNP) | VAF 160/604 reads (26%) | called by muse, mutect2, varscan2
- SLC35C2 | c.972T>C p.D324= | Silent (SNP) | VAF 25/209 reads (12%) | called by muse, mutect2, varscan2
- SLCO2B1 | c.2094G>C p.S698= | Silent (SNP) | VAF 46/299 reads (15%) | called by muse, mutect2, varscan2
- SP8 | c.246G>A p.L82= (on ENST00000361443 / NM_198956.4; = p.L100= on NM_182700.6) | Silent (SNP) | VAF 48/258 reads (19%) | catalogued as rs1431061137; called by muse, varscan2
- SPO11 | c.120C>A p.R40= | Silent (SNP) | VAF 50/288 reads (17%) | called by muse, mutect2, varscan2
- SYMPK | c.3058C>T p.L1020= | Silent (SNP) | VAF 47/392 reads (12%) | called by muse, mutect2, varscan2
- TAF1 | c.90G>A p.G30= | Silent (SNP) | VAF 26/384 reads (7%) | catalogued as rs1343859273; called by muse, mutect2
- TAS2R1 | c.450T>C p.F150= | Silent (SNP) | VAF 75/370 reads (20%) | called by muse, mutect2, varscan2
- TBC1D24 | c.807C>T p.I269= | Silent (SNP) | VAF 112/430 reads (26%) | catalogued as rs762576413, COSV53547824; called by muse, mutect2, varscan2
- TBX21 | c.1354C>A p.R452= | Silent (SNP) | VAF 137/638 reads (21%) | catalogued as rs540412579; called by muse, mutect2, varscan2
- TBX3 | c.1476C>T p.H492= (on ENST00000257566 / NM_016569.4; = p.H472= on NM_005996.4) | Silent (SNP) | VAF 174/829 reads (21%) | called by muse, mutect2, varscan2
- TEX13A | c.603G>A p.E201= | Silent (SNP) | VAF 62/650 reads (10%) | catalogued as rs782092010; called by muse, mutect2
- TMEM221 | c.804G>T p.G268= | Silent (SNP) | VAF 103/504 reads (20%) | called by muse, mutect2, varscan2
- TMEM38B | c.666C>T p.T222= | Silent (SNP) | VAF 23/215 reads (11%) | called by muse, mutect2, varscan2
- TNC | c.4203T>C p.A1401= | Silent (SNP) | VAF 41/356 reads (12%) | called by muse, mutect2, varscan2
- TRIM58 | c.1287T>C p.D429= | Silent (SNP) | VAF 63/678 reads (9%) | catalogued as COSV63569123; called by muse, mutect2
- TTN | c.98838T>G p.V32946= (on ENST00000591111; = p.V25522= on NM_003319.4) | Silent (SNP) | VAF 39/296 reads (13%) | called by muse, mutect2, varscan2
- TTN | c.52500C>G p.T17500= (on ENST00000591111; = p.T10076= on NM_003319.4) | Silent (SNP) | VAF 84/497 reads (17%) | called by muse, mutect2, varscan2
- TUBGCP6 | c.15G>T p.T5= | Silent (SNP) | VAF 46/378 reads (12%) | called by muse, mutect2
56 further variants in this file (0 protein-altering or splice-affecting, 17 silent, 39 other) are not listed here.
